Somatic mutation profile of tumor specimen TCGA-BR-8591-01A (aliquot TCGA-BR-8591-01A-11D-2394-08) from TCGA case TCGA-BR-8591, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 79.5 years (29,054 days).
Specimen TCGA-BR-8591-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0eef70e6-29d1-4edd-9226-c777676fa0e8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-8591-10A (Blood Derived Normal), aliquot TCGA-BR-8591-10A-01D-2394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/264b54f9-5d9c-4fa0-909b-57f0b9050cae

The open-access MAF lists 1,792 somatic variants for this specimen: 1,383 protein-altering or splice-affecting, 369 silent, 40 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 896, Silent 369, Frame Shift Del 328, Frame Shift Ins 74, Nonsense Mutation 35, Splice Site 30, Intron 19, Splice Region 11, RNA 10, In Frame Del 9, 3'UTR 4, 3'Flank 3.

Variants (750 of 1,792; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTN1 | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as rs387907348, CM138025, COSV51993463; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AP1S1 | c.364del p.D122Mfs*11 | Frame Shift Del (DEL) | VAF 12/53 reads (23%) | catalogued as rs767358930; ClinVar: likely pathogenic; called by mutect2, varscan2
- B2M | c.68-2A>G p.X23_splice | Splice Site (SNP) | VAF 23/120 reads (19%) | hotspot (GDC flag); catalogued as rs111482205, COSV62562974, COSV62564351; called by muse, mutect2, varscan2
- CHD2 | c.522del p.V175* | Frame Shift Del (DEL) | VAF 18/35 reads (51%) | catalogued as rs748694853; ClinVar: likely pathogenic; called by mutect2, varscan2
- CNGB3 | c.1285del p.S429Lfs*9 | Frame Shift Del (DEL) | VAF 6/33 reads (18%) | catalogued as rs776896038; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- COL11A2 | c.966dup p.T323Hfs*19 | Frame Shift Ins (INS) | VAF 18/80 reads (23%) | catalogued as rs748440351; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by mutect2, varscan2
- FLNB | c.1592del p.G531Dfs*42 | Frame Shift Del (DEL) | VAF 28/110 reads (25%) | catalogued as rs746105983; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KMT2B | c.521del p.P174Qfs*20 | Frame Shift Del (DEL) | VAF 44/159 reads (28%) | catalogued as rs763183959; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KRT10 | c.449T>C p.M150T | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs58901407, CM941004, CM941005, COSV54091035; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MFRP | c.3del p.H2Tfs*100 (on ENST00000449574; = p.H384Tfs*94 on NM_031433.4) | Frame Shift Del (DEL) | VAF 8/31 reads (26%) | catalogued as rs587776595; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 50/110 reads (45%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- MYH7 | c.2539_2541del p.K847del | In Frame Del (DEL) | VAF 35/151 reads (23%) | catalogued as rs397516155; ClinVar: uncertain significance / likely pathogenic; called by mutect2, pindel, varscan2
- PALB2 | c.3026del p.P1009Lfs*6 | Frame Shift Del (DEL) | VAF 17/66 reads (26%) | catalogued as rs180177131, CD111016; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 31/118 reads (26%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1132T>C p.C378R | Missense Mutation (SNP) | VAF 24/87 reads (28%) | hotspot (GDC flag); SIFT tolerated (0.31); PolyPhen possibly damaging (0.715); catalogued as COSV55882697; called by muse, mutect2, varscan2
- PXDN | c.2568del p.C857Afs*5 | Frame Shift Del (DEL) | VAF 8/44 reads (18%) | catalogued as rs558163499, CD117085; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SMPD1 | c.996del p.F333Sfs*52 | Frame Shift Del (DEL) | VAF 15/81 reads (19%) | catalogued as rs387906289; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCA1 | c.4219G>A p.A1407T | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.119); catalogued as rs189206655, COSV66064966; called by muse, mutect2, varscan2
- ABCA10 | c.3502G>A p.E1168K | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.567); catalogued as rs150472849; called by muse, mutect2, varscan2
- ABCA12 | c.3253G>T p.V1085L (on ENST00000272895 / NM_173076.3; = p.V767L on NM_015657.3) | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV55965092; called by muse, mutect2, varscan2
- ABCA2 | c.3175G>A p.A1059T (on ENST00000614293; = p.A1029T on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55805073; called by muse, mutect2, varscan2
- ABCC11 | c.626T>C p.L209P | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62325182; called by muse, mutect2
- ABCC3 | c.2272C>T p.R758W | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs376756717; called by muse, mutect2, varscan2
- ABI3BP | c.338G>A p.R113H | Missense Mutation (SNP) | VAF 42/180 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs182876905, COSV52537519, COSV99428471; called by muse, mutect2, varscan2
- ABRAXAS2 | c.74A>G p.E25G | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53718118; called by muse, mutect2
- AC007040.2 | c.191G>A p.R64H | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs782138539, COSV55592904; called by muse, mutect2, varscan2
- AC013489.1 | c.743G>A p.G248D | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV51552975, COSV99183917; called by muse, mutect2, varscan2
- AC093155.3 | c.793C>T p.R265W | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs892465103, COSV63350967; called by muse, mutect2, varscan2
- AC098582.1 | c.331G>A p.G111R | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.157); catalogued as COSV52023541, COSV52025553; called by muse, mutect2, varscan2
- ACAN | c.5222G>T p.G1741V | Missense Mutation (SNP) | VAF 37/172 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV61366970; called by muse, mutect2, varscan2
- ACER1 | c.176T>C p.I59T | Missense Mutation (SNP) | VAF 56/226 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.197); catalogued as COSV56836556; called by muse, mutect2, varscan2
- ACOT2 | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.047); catalogued as rs1417226886, COSV53151240; called by muse, mutect2
- ACOX3 | c.781G>A p.A261T | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.024); catalogued as rs193103573; called by muse, mutect2, varscan2
- ACSM2A | c.584A>C p.K195T (on ENST00000219054; = p.K116T on NM_001308169.2) | Missense Mutation (SNP) | VAF 12/237 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.058); catalogued as COSV54586469, COSV54589383; called by muse, mutect2
- ACTN1 | c.2582T>C p.I861T | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.531); catalogued as COSV51995999; called by muse, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 24/90 reads (27%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAL | c.651dup p.E218Rfs*11 | Frame Shift Ins (INS) | VAF 16/66 reads (24%) | catalogued as rs778831705; called by mutect2, varscan2
- ADAM21 | c.340T>C p.Y114H | Missense Mutation (SNP) | VAF 33/207 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.05); catalogued as COSV50804182; called by muse, varscan2
- ADAM23 | c.2340dup p.K781Qfs*3 | Frame Shift Ins (INS) | VAF 14/56 reads (25%) | catalogued as rs767549806; called by mutect2, varscan2
- ADAMTS14 | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.036); catalogued as COSV100941385, COSV64605277; called by muse, mutect2, varscan2
- ADAMTS18 | c.1223C>T p.A408V | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51421056; called by muse, mutect2, varscan2
- ADAMTS2 | c.3218T>C p.M1073T | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.15); catalogued as COSV52388052; called by muse, mutect2, varscan2
- ADAMTS2 | c.2210-2del p.X737_splice | Splice Site (DEL) | VAF 13/48 reads (27%) | catalogued as rs1219329381; called by mutect2, pindel, varscan2
- ADAMTS9 | c.4874C>T p.S1625L | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as rs764052034, COSV55787726; called by muse, mutect2, varscan2
- ADAMTSL1 | c.97G>A p.D33N | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.318); catalogued as COSV52822067; called by muse, mutect2, varscan2
- ADARB1 | c.1630G>A p.G544R (on ENST00000360697 / NM_001346687.2; = p.G504R on NM_001112.4) | Missense Mutation (SNP) | VAF 52/220 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as rs757268939, COSV62347128; called by muse, mutect2, varscan2
- ADCY5 | c.1534C>T p.R512C | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59202522; called by muse, mutect2, varscan2
- ADCY8 | c.788G>A p.G263D | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.497); catalogued as rs1198200451, COSV53905866; called by muse, mutect2, varscan2
- ADD2 | c.473C>T p.T158M | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1553372657, COSV52463844; called by muse, mutect2, varscan2
- ADD3 | c.2102del p.K701Rfs*8 (on ENST00000356080 / NM_001320591.2; = p.K669Rfs*8 on NM_001121.4) | Frame Shift Del (DEL) | VAF 35/77 reads (45%) | catalogued as rs760140619; called by mutect2, varscan2
- ADGRB2 | c.1454G>A p.S485N | Missense Mutation (SNP) | VAF 33/142 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV57077394; called by muse, mutect2, varscan2
- ADGRF5 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs780842238, COSV51938421; called by muse, mutect2, varscan2
- ADGRG4 | c.5645C>T p.S1882F | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54963948; called by muse, mutect2
- ADRA2B | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69787168; called by muse, mutect2, varscan2
- ADRB1 | c.811C>T p.R271W | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.711); catalogued as COSV65168247; called by muse, mutect2
- AGAP1 | c.955A>G p.T319A | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.226); catalogued as COSV58336330; called by muse, mutect2
- AGO2 | c.1806del p.A603Pfs*92 | Frame Shift Del (DEL) | VAF 56/334 reads (17%) | catalogued as rs748399150; called by mutect2, varscan2
- AGO4 | c.419A>G p.H140R | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1306100208, COSV64618241; called by muse, mutect2, varscan2
- AHCTF1 | c.4822A>G p.T1608A (on ENST00000366508; = p.T1582A on NM_015446.5) | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV58253641; called by muse, mutect2, varscan2
- AIFM3 | c.1264G>A p.V422I | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.472); catalogued as rs774742086, COSV53150302; called by muse, mutect2, varscan2
- AK8 | c.333+2T>C p.X111_splice | Splice Site (SNP) | VAF 5/33 reads (15%) | catalogued as COSV53758841; called by muse, mutect2, varscan2
- AK9 | c.3625del p.R1209Gfs*39 | Frame Shift Del (DEL) | VAF 11/56 reads (20%) | catalogued as rs778351035; called by mutect2, pindel, varscan2
- AKAP3 | c.751G>A p.G251R | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.063); catalogued as rs753033294, COSV57419427; called by muse, mutect2, varscan2
- AKAP4 | c.128G>A p.C43Y | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV62073864; called by muse, mutect2, varscan2
- ALDH2 | c.166A>G p.T56A | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.097); catalogued as COSV55670223; called by muse, mutect2, varscan2
- ALDH6A1 | c.448A>G p.S150G | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as COSV63247129; called by muse, mutect2, varscan2
- ALPI | c.1433C>T p.A478V | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV55013363; called by muse, mutect2
- ALPK2 | c.3515C>T p.T1172M | Missense Mutation (SNP) | VAF 46/156 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs140868694; called by muse, mutect2, varscan2
- AMOT | c.1478T>C p.M493T (on ENST00000371959 / NM_001113490.1; = p.M84T on NM_133265.3) | Missense Mutation (SNP) | VAF 60/120 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV59061012; called by muse, mutect2, varscan2
- ANGEL1 | c.1513C>T p.R505C | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.636); catalogued as rs773527799, COSV51874413; called by muse, mutect2, varscan2
- ANK1 | c.3499A>G p.T1167A | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as COSV55891537; called by muse, mutect2
- ANK3 | c.2975C>T p.A992V (on ENST00000280772 / NM_001320874.2; = p.A126V on NM_001149.3) | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55075206; called by muse, mutect2, varscan2
- ANK3 | c.1718C>T p.A573V | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1225954107, COSV99779581; called by muse, varscan2
- ANKHD1-EIF4EBP3 | c.4517C>G p.P1506R | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV51855503; called by muse, mutect2, varscan2
- ANKLE2 | c.1610A>C p.K537T | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.218); catalogued as COSV61710900, COSV61711037; called by muse, mutect2, varscan2
- ANKRD10 | c.614A>G p.H205R | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV57445036; called by muse, mutect2, varscan2
- ANO5 | c.683T>C p.I228T | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV61088957; called by muse, mutect2, varscan2
- AOX1 | c.1909G>T p.G637C | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65980752, COSV65983407; called by muse, mutect2, varscan2
- APBA1 | c.1849A>G p.R617G | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs951156535, COSV55234629; called by muse, mutect2, varscan2
- APBA1 | c.1384G>A p.A462T | Missense Mutation (SNP) | VAF 76/296 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV55234644; called by muse, mutect2, varscan2
- APOBEC3B | c.430C>A p.R144S | Missense Mutation (SNP) | VAF 41/151 reads (27%) | SIFT tolerated (0.6); PolyPhen benign (0.173); catalogued as COSV59841826; called by muse, mutect2, varscan2
- APOM | c.472G>A p.V158M | Missense Mutation (SNP) | VAF 64/237 reads (27%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); catalogued as rs750264591, COSV52993890; called by muse, mutect2, varscan2
- ARFGAP3 | c.896del p.N299Mfs*22 | Frame Shift Del (DEL) | VAF 40/150 reads (27%) | catalogued as rs774441374, COSV54310368; called by mutect2, varscan2
- ARHGAP17 | c.2471G>A p.S824N (on ENST00000289968 / NM_001006634.3; = p.S746N on NM_018054.6) | Missense Mutation (SNP) | VAF 78/296 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV51510822; called by muse, mutect2, varscan2
- ARHGAP28 | c.1288A>T p.K430* (on ENST00000383472 / NM_001366230.1; = p.K271* on NM_001010000.3) | Nonsense Mutation (SNP) | VAF 17/42 reads (40%) | catalogued as COSV51644086; called by muse, mutect2, varscan2
- ARHGAP31 | c.1433G>A p.R478H | Missense Mutation (SNP) | VAF 43/181 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as rs376265481; called by muse, mutect2, varscan2
- ARHGAP32 | c.4073C>T p.A1358V (on ENST00000310343 / NM_001378025.1; = p.A1009V on NM_014715.4) | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs763252101, COSV59852325; called by muse, mutect2, varscan2
- ARHGEF1 | c.1618G>A p.V540M | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.397); catalogued as COSV61529066; called by muse, mutect2, varscan2
- ARHGEF10L | c.852G>C p.E284D | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.457); catalogued as rs757063935, COSV51434566; called by muse, mutect2, varscan2
- ARHGEF17 | c.1625G>A p.R542Q | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs781760252, COSV55232161, COSV99735331; called by muse, mutect2, varscan2
- ARHGEF40 | c.2209del p.A737Pfs*3 | Frame Shift Del (DEL) | VAF 32/160 reads (20%) | catalogued as rs749402223; called by mutect2, pindel, varscan2
- ARHGEF6 | c.1585C>A p.H529N | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.093); catalogued as COSV51694622; called by muse, mutect2, varscan2
- ARID4A | c.1266del p.D423Tfs*2 | Frame Shift Del (DEL) | VAF 10/52 reads (19%) | catalogued as rs776520069; called by mutect2, varscan2
- ARMC6 | c.511G>A p.D171N (on ENST00000392336; = p.D146N on NM_033415.4) | Missense Mutation (SNP) | VAF 4/76 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.9); catalogued as COSV54183531; called by muse, mutect2
- ARMC8 | c.1134+5G>A | Splice Region (SNP) | VAF 14/71 reads (20%) | catalogued as rs779134602, COSV100627609; called by muse, mutect2, varscan2
- ARNT2 | c.1271A>G p.Y424C | Missense Mutation (SNP) | VAF 75/272 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.165); catalogued as rs1371434647, COSV57589193; called by muse, mutect2, varscan2
- ARV1 | c.518del p.K173Sfs*8 | Frame Shift Del (DEL) | VAF 24/50 reads (48%) | catalogued as rs544784472, COSV59618356; called by mutect2, varscan2
- ARVCF | c.455G>A p.G152D | Missense Mutation (SNP) | VAF 38/142 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as COSV54266230, COSV54269172; called by muse, mutect2, varscan2
- ASAP3 | c.1627C>T p.R543W | Missense Mutation (SNP) | VAF 60/235 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as rs766259434, COSV60876406; called by muse, mutect2, varscan2
- ASB7 | c.119C>T p.P40L | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.995); catalogued as COSV58403200, COSV58403717; called by muse, mutect2, varscan2
- ASCC2 | c.209T>G p.L70R | Missense Mutation (SNP) | VAF 39/142 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57075894; called by muse, mutect2, varscan2
- ASL | c.1210G>A p.A404T | Missense Mutation (SNP) | VAF 52/181 reads (29%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs757216794, COSV59189145; called by muse, mutect2, varscan2
- ATM | c.3283A>G p.R1095G | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.021); catalogued as COSV53765520; called by muse, mutect2, varscan2
- ATP10A | c.2903G>A p.R968H | Missense Mutation (SNP) | VAF 39/134 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.031); catalogued as rs150976669; called by muse, mutect2, varscan2
- ATP10D | c.1070A>G p.E357G | Missense Mutation (SNP) | VAF 49/191 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.013); catalogued as COSV56711600; called by muse, mutect2, varscan2
- ATP10D | c.1848del p.L617Cfs*41 | Frame Shift Del (DEL) | VAF 13/52 reads (25%) | catalogued as rs764067652, COSV56705401; called by mutect2, varscan2
- ATP4A | c.1058T>G p.V353G | Missense Mutation (SNP) | VAF 33/207 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV52870822; called by muse, mutect2, varscan2
- ATP7B | c.4274T>C p.V1425A | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.103); catalogued as COSV54442125; called by muse, mutect2, varscan2
- ATP8B3 | c.2714A>G p.K905R | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV59547046; called by muse, mutect2, varscan2
- ATP9A | c.2338A>G p.T780A | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.479); catalogued as rs755673645, COSV58770374; called by muse, mutect2, varscan2
- ATP9A | c.116G>A p.R39H | Missense Mutation (SNP) | VAF 44/179 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1194861517, COSV58762840, COSV58770385; called by muse, mutect2, varscan2
- B4GALNT4 | c.2090G>A p.R697H | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57325520; called by muse, mutect2
- BBS5 | c.770A>G p.Y257C | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs376537695; called by muse, mutect2, varscan2
- BCAT1 | c.65T>C p.V22A | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV53915970; called by muse, mutect2, varscan2
- BCHE | c.1262_1264del p.V421del | In Frame Del (DEL) | VAF 24/98 reads (24%) | catalogued as rs1398106709; called by pindel, varscan2
- BCL7C | c.358del p.Q120Sfs*33 | Frame Shift Del (DEL) | VAF 38/118 reads (32%) | catalogued as rs758526156; called by mutect2, pindel, varscan2
- BCL9 | c.860C>A p.P287H | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.275); catalogued as COSV52348794; called by muse, mutect2, varscan2
- BCL9 | c.3688G>A p.G1230R | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as rs587726690, COSV52347771; called by muse, mutect2, varscan2
- BCL9L | c.3862C>T p.R1288C | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as rs566574462, COSV52688055; called by muse, mutect2, varscan2
- BDP1 | c.1214T>C p.V405A | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV62433506; called by muse, mutect2
- BFSP1 | c.923G>A p.R308Q | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs766607722, COSV64901464; called by muse, mutect2, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 20/91 reads (22%) | catalogued as rs772920507, COSV65808737; called by mutect2, pindel, varscan2
- BNC2 | c.2542G>A p.V848M | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.132); catalogued as COSV66154404; called by muse, mutect2, varscan2
- BOD1L1 | c.6207A>C p.K2069N | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV50041173; called by muse, mutect2, varscan2
- BRAF | c.2343G>T p.E781D (on ENST00000288602 / NM_001374244.1; = p.E741D on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 58/186 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0.024); catalogued as COSV56319179; called by muse, varscan2
- BRCA1 | c.4496C>T p.S1499F | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.854); catalogued as rs1286565832, COSV58796590; called by muse, mutect2, varscan2
- BRD8 | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs766696343, COSV50163449; called by muse, mutect2, varscan2
- BRINP1 | c.1841C>T p.T614M | Missense Mutation (SNP) | VAF 44/184 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56296920; called by muse, mutect2, varscan2
- BRINP2 | c.1811C>A p.P604H | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64179447; called by muse, mutect2, varscan2
- BTN2A1 | c.638C>A p.S213Y | Missense Mutation (SNP) | VAF 60/214 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as COSV57005639; called by muse, mutect2, varscan2
- C16orf70 | c.1230del p.R411Gfs*6 | Frame Shift Del (DEL) | VAF 43/188 reads (23%) | catalogued as rs539297455, COSV54625370; called by mutect2, pindel, varscan2
- C16orf71 | c.739C>T p.P247S | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as COSV54794482; called by muse, mutect2, varscan2
- C19orf12 | c.314C>T p.A105V (on ENST00000392278 / NM_001031726.3; = p.A94V on NM_031448.6) | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.545); catalogued as rs61750862, COSV60365518; called by muse, varscan2
- C19orf12 | c.210del p.L71Cfs*2 (on ENST00000392278 / NM_001031726.3; = p.L60Cfs*2 on NM_031448.6) | Frame Shift Del (DEL) | VAF 42/196 reads (21%) | catalogued as rs770374870; called by pindel, varscan2
- C1QTNF6 | c.235C>T p.R79C | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs751594408, COSV55397185; called by muse, mutect2, varscan2
- C1orf100 | c.86T>C p.V29A | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.124); catalogued as COSV57373646; called by muse, mutect2, varscan2
- C1orf174 | c.55C>T p.R19* | Nonsense Mutation (SNP) | VAF 11/58 reads (19%) | catalogued as rs866001822, COSV64366050; called by muse, mutect2, varscan2
- C1orf226 | c.303G>A p.W101* | Nonsense Mutation (SNP) | VAF 6/13 reads (46%) | catalogued as rs1028088717, COSV63396456; called by muse, mutect2, varscan2
- C2CD6 | c.1855del p.I619Lfs*19 | Frame Shift Del (DEL) | VAF 27/97 reads (28%) | catalogued as rs752496395; called by mutect2, varscan2
- C3orf33 | c.338C>T p.A113V (on ENST00000340171 / NM_001308229.2; = p.A70V on NM_173657.2) | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV60897968; called by muse, mutect2
- C9orf116 | c.392G>T p.R131M | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.116); catalogued as COSV65646590; called by muse, mutect2, varscan2
- CABIN1 | c.3662A>C p.Q1221P | Missense Mutation (SNP) | VAF 50/154 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.593); catalogued as COSV54087238; called by muse, mutect2, varscan2
- CACNA1B | c.6734G>A p.S2245N | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.039); catalogued as COSV53142017; called by muse, mutect2, varscan2
- CACNA1E | c.5011T>C p.S1671P | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62411782; called by muse, mutect2, varscan2
- CACNA2D2 | c.773G>T p.R258L | Missense Mutation (SNP) | VAF 43/133 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as COSV56567693, COSV99817327; called by muse, mutect2, varscan2
- CACNA2D4 | c.3137C>T p.P1046L | Missense Mutation (SNP) | VAF 33/153 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.073); catalogued as COSV54957215; called by muse, mutect2, varscan2
- CACNB2 | c.731G>A p.R244H (on ENST00000324631 / NM_201596.3; = p.R189H on NM_000724.4) | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as rs1291633086, COSV56640459; called by muse, mutect2, varscan2
- CACNG7 | c.570+2T>C p.X190_splice | Splice Site (SNP) | VAF 40/155 reads (26%) | catalogued as COSV55816655; called by muse, mutect2, varscan2
- CADM2 | c.583A>T p.S195C (on ENST00000407528 / NM_001167674.2; = p.S197C on NM_153184.4) | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV67395399; called by muse, mutect2, varscan2
- CALR3 | c.485G>A p.R162K | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.017); catalogued as COSV54171472; called by muse, mutect2
- CAMSAP1 | c.3274dup p.R1092Pfs*30 | Frame Shift Ins (INS) | VAF 15/70 reads (21%) | catalogued as rs757550050; called by mutect2, pindel, varscan2
- CAMSAP3 | c.1325C>T p.P442L | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs769372763, COSV50348787; called by muse, mutect2, varscan2
- CAPS | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 44/183 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.402); catalogued as rs749793356, COSV50384762; called by muse, mutect2, varscan2
- CARD11 | c.3259A>G p.R1087G | Missense Mutation (SNP) | VAF 75/130 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV67801419; called by muse, mutect2, varscan2
- CASC3 | c.1679A>G p.H560R | Missense Mutation (SNP) | VAF 53/234 reads (23%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.991); catalogued as COSV52868853; called by muse, mutect2, varscan2
- CASKIN2 | c.2182dup p.Q728Pfs*14 | Frame Shift Ins (INS) | VAF 24/78 reads (31%) | catalogued as rs751998890; called by mutect2, varscan2
- CASS4 | c.791C>T p.A264V | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs367625281; called by muse, mutect2, varscan2
- CASS4 | c.2239G>A p.V747I | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as rs534377125, COSV64387906; called by muse, mutect2, varscan2
- CATSPERB | c.978G>T p.E326D | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV56432351; called by muse, mutect2
- CCDC13 | c.514-2A>G p.X172_splice | Splice Site (SNP) | VAF 19/96 reads (20%) | catalogued as COSV59608784; called by muse, mutect2, varscan2
- CCDC138 | c.413C>T p.T138M | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs776055875, COSV54570768; called by muse, mutect2, varscan2
- CCDC151 | c.874C>T p.R292* | Nonsense Mutation (SNP) | VAF 14/56 reads (25%) | catalogued as rs1308843878, COSV62699102; called by muse, mutect2
- CCDC3 | c.504G>T p.Q168H | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.006); catalogued as COSV66561254; called by muse, mutect2, varscan2
- CCDC97 | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.041); catalogued as rs1286685402, COSV54189870; called by muse, mutect2, varscan2
- CCDC97 | c.607C>A p.P203T | Missense Mutation (SNP) | VAF 49/168 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.245); catalogued as COSV54191131, COSV54191375; called by muse, mutect2, varscan2
- CCDC9B | c.294dup p.M99Dfs*12 | Frame Shift Ins (INS) | VAF 32/120 reads (27%) | catalogued as rs765438623; called by mutect2, varscan2
- CCKAR | c.1206G>T p.E402D | Missense Mutation (SNP) | VAF 38/145 reads (26%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as COSV55163222; called by muse, mutect2, varscan2
- CD1C | c.956T>A p.L319H | Missense Mutation (SNP) | VAF 20/202 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV63807255; called by muse, mutect2, varscan2
- CD276 | c.1495_1497del p.E499del (on ENST00000318443 / NM_001024736.2; = p.E281del on NM_025240.2 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 9/33 reads (27%) | catalogued as rs772709455; called by pindel, varscan2
- CD79B | c.275A>G p.E92G | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.014); catalogued as COSV50080375; called by muse, mutect2, varscan2
- CD82 | c.700G>A p.V234M | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs755430626, COSV57036874, COSV99907897; called by muse, mutect2, varscan2
- CDC7 | c.92del p.N31Tfs*51 | Frame Shift Del (DEL) | VAF 26/117 reads (22%) | catalogued as rs762194001; called by mutect2, varscan2
- CDCA2 | c.403T>C p.Y135H | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.073); catalogued as COSV57947930; called by muse, mutect2, varscan2
- CDH10 | c.2312G>A p.R771Q | Missense Mutation (SNP) | VAF 49/184 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.627); catalogued as rs774023585, COSV52592676; called by muse, mutect2, varscan2
- CDH23 | c.347G>A p.R116Q | Missense Mutation (SNP) | VAF 40/184 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0.408); catalogued as rs1305672343, COSV54947164, COSV99820158; called by muse, mutect2
- CDRT1 | c.61G>A p.D21N | Missense Mutation (SNP) | VAF 37/373 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs375341389; called by muse, mutect2, varscan2
- CDS1 | c.236T>C p.L79S | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55690083; called by muse, mutect2, varscan2
- CEACAM3 | c.347A>C p.D116A | Missense Mutation (SNP) | VAF 80/333 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV55762896, COSV99705095; called by muse, mutect2, varscan2
- CEBPZ | c.1428del p.D477Mfs*11 | Frame Shift Del (DEL) | VAF 10/42 reads (24%) | catalogued as rs763090473; called by mutect2, varscan2
- CELSR2 | c.7249G>A p.A2417T | Missense Mutation (SNP) | VAF 35/160 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.05); catalogued as COSV54777588; called by muse, mutect2, varscan2
- CEP135 | c.575A>G p.D192G | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57262089; called by muse, mutect2, varscan2
- CEP170B | c.3955G>A p.V1319M (on ENST00000453495; = p.V1248M on NM_015005.3) | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.493); catalogued as rs761333323, COSV52045398; called by muse, mutect2, varscan2
- CEP250 | c.5532G>T p.Q1844H | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.535); catalogued as COSV61172970; called by mutect2, varscan2
- CEP290 | c.635del p.N212Tfs*14 | Frame Shift Del (DEL) | VAF 37/114 reads (32%) | catalogued as rs769091629, COSV99063658; called by mutect2, varscan2
- CERS5 | c.1046G>A p.R349H | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV58190080; called by muse, mutect2, varscan2
- CES3 | c.1346C>T p.A449V | Missense Mutation (SNP) | VAF 96/361 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as rs377199306, COSV57594620; called by muse, mutect2, varscan2
- CETP | c.122A>G p.N41S | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.107); catalogued as COSV52363885; called by muse, mutect2, varscan2
- CHD6 | c.2042G>T p.R681L | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV58560877; called by muse, mutect2, varscan2
- CHD7 | c.5053T>C p.L1685= | Splice Region (SNP) | VAF 27/99 reads (27%) | catalogued as COSV71113519; called by muse, mutect2, varscan2
- CHEK1 | c.1324C>T p.R442W | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs968420616, COSV54025121; called by muse, mutect2, varscan2
- CHMP1A | c.404C>T p.S135L | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.278); catalogued as rs776834821, COSV53684200; called by muse, mutect2, varscan2
- CHRM2 | c.439G>A p.A147T | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV57781204; called by muse, mutect2, varscan2
- CHRNA7 | c.1060C>T p.R354C | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as rs568931594, COSV60974599; called by muse, varscan2
- CHST13 | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.028); catalogued as rs1270912291, COSV60041405; called by muse, mutect2
- CILP2 | c.1675C>A p.P559T | Missense Mutation (SNP) | VAF 45/186 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.662); catalogued as COSV52278931; called by muse, mutect2, varscan2
- CIZ1 | c.1338G>T p.Q446H | Missense Mutation (SNP) | VAF 69/258 reads (27%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.359); catalogued as rs989474466, COSV52973778; called by muse, mutect2, varscan2
- CKAP2 | c.1973T>C p.L658S (on ENST00000378037 / NM_001098525.2; = p.L657S on NM_018204.5) | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51623914; called by muse, mutect2, varscan2
- CKLF | c.447del p.E150Kfs*? (on ENST00000264001 / NM_016951.4; = p.E65Kfs*? on NM_016326.3) | Frame Shift Del (DEL) | VAF 33/106 reads (31%) | catalogued as rs754415052; called by mutect2, varscan2
- CLEC3A | c.235C>T p.R79* (on ENST00000651443; = p.R70* on NM_005752.6) | Nonsense Mutation (SNP) | VAF 21/194 reads (11%) | catalogued as rs771902356, COSV55223012; called by muse, mutect2, varscan2
- CLN8 | c.84G>T p.M28I | Missense Mutation (SNP) | VAF 35/169 reads (21%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV58670703, COSV58671274; called by muse, mutect2, varscan2
- CLOCK | c.368del p.L123* | Frame Shift Del (DEL) | VAF 15/74 reads (20%) | catalogued as rs369752219; called by mutect2, varscan2
- CLPB | c.2106G>T p.K702N | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.005); catalogued as COSV53632382; called by muse, mutect2, varscan2
- CLSTN2 | c.2525G>A p.C842Y | Missense Mutation (SNP) | VAF 68/228 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as COSV71723875; called by muse, mutect2
- CLSTN3 | c.1793C>T p.T598I | Missense Mutation (SNP) | VAF 58/217 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.084); catalogued as rs1224936159, COSV56939384; called by muse, mutect2, varscan2
- CLTCL1 | c.4368G>T p.Q1456H | Missense Mutation (SNP) | VAF 64/272 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54236960; called by muse, mutect2, varscan2
- CNOT1 | c.5988G>A p.M1996I | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.246); catalogued as COSV55320835; called by muse, mutect2, varscan2
- CNR1 | c.320G>T p.C107F | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.898); catalogued as COSV62990590; called by muse, mutect2, varscan2
- CNTNAP1 | c.1114G>A p.V372I | Missense Mutation (SNP) | VAF 59/197 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs879724262, COSV52853227; called by muse, mutect2, varscan2
- CNTNAP2 | c.1520A>T p.N507I | Missense Mutation (SNP) | VAF 46/172 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.11); catalogued as COSV62154563, COSV62237131; called by muse, mutect2, varscan2
- COL12A1 | c.9077del p.P3026Lfs*51 | Frame Shift Del (DEL) | VAF 20/110 reads (18%) | catalogued as rs1243039688; called by mutect2, pindel, varscan2
- COL12A1 | c.9002G>C p.G3001A | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV59394651, COSV59404398; called by muse, mutect2, varscan2
- COL4A5 | c.2968C>T p.P990S | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.185); catalogued as COSV60368474, COSV60374628; called by muse, mutect2, varscan2
- COL5A2 | c.2563G>A p.G855R | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1064795616, COSV66413410; ClinVar: uncertain significance; called by muse, mutect2
- COL6A6 | c.1081A>G p.T361A | Missense Mutation (SNP) | VAF 45/213 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV62033707; called by muse, mutect2, varscan2
- COL7A1 | c.2428G>T p.G810C | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60401087; called by muse, mutect2, varscan2
- COLGALT1 | c.737C>T p.A246V | Missense Mutation (SNP) | VAF 41/136 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); catalogued as rs759308497, COSV53110947; called by muse, mutect2, varscan2
- COQ8A | c.479G>A p.R160Q | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0.018); catalogued as rs780563486, COSV64658842; called by muse, mutect2, varscan2
- CORO1B | c.623G>A p.G208D | Missense Mutation (SNP) | VAF 50/181 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as COSV58171622; called by muse, mutect2, varscan2
- CPB2 | c.790T>C p.W264R | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867373750, COSV51676568; called by muse, mutect2, varscan2
- CPEB4 | c.1490C>A p.P497H | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as rs948731859, COSV54175131, COSV99437798; called by muse, mutect2, varscan2
- CPNE1 | c.1088A>G p.N363S (on ENST00000352393; = p.N368S on NM_003915.5) | Missense Mutation (SNP) | VAF 11/180 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.012); catalogued as COSV58294043; called by muse, mutect2
- CPNE7 | c.385G>A p.V129M | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs745389352, COSV52015847, COSV52017233; called by muse, mutect2, varscan2
- CRACDL | c.1196C>T p.A399V | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.098); catalogued as COSV67408567, COSV67409655; called by muse, mutect2, varscan2
- CRB2 | c.2200G>A p.G734R | Missense Mutation (SNP) | VAF 44/168 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.025); catalogued as rs369985658; called by muse, mutect2, varscan2
- CRB2 | c.2576G>A p.C859Y | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368104093; called by muse, mutect2, varscan2
- CRTC1 | c.940C>G p.L314V | Missense Mutation (SNP) | VAF 75/239 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.658); catalogued as rs774556926, COSV58717766, COSV58722082; called by muse, mutect2, varscan2
- CSMD3 | c.9916A>G p.S3306G (on ENST00000297405 / NM_001363185.1; = p.S3137G on NM_052900.3) | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.9); PolyPhen probably damaging (0.978); catalogued as COSV52278337; called by muse, mutect2, varscan2
- CSMD3 | c.1325C>A p.A442E | Missense Mutation (SNP) | VAF 26/178 reads (15%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.979); catalogued as COSV52278357; called by muse, mutect2, varscan2
- CTBP1 | c.965A>G p.Q322R | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.559); catalogued as COSV52075804; called by muse, mutect2, varscan2
- CTC1 | c.2996C>T p.P999L | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs780572571, COSV59854756; called by muse, mutect2, varscan2
- CTR9 | c.2707A>G p.R903G | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV63729115, COSV63729385; called by muse, mutect2, varscan2
- CTU2 | c.913C>T p.R305W | Missense Mutation (SNP) | VAF 44/160 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370063135; called by muse, mutect2, varscan2
- CYLD | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.14); catalogued as rs763792744, COSV61096813; called by muse, mutect2, varscan2
- CYP2A7 | c.1061C>T p.A354V | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99394014; called by muse, mutect2, varscan2
- CYP2U1 | c.1570C>A p.L524M | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.028); catalogued as COSV60549502; called by muse, mutect2, varscan2
- CYREN | c.389del p.G130Vfs*19 | Frame Shift Del (DEL) | VAF 39/160 reads (24%) | catalogued as rs753942205; called by mutect2, pindel, varscan2
- DAGLB | c.480del p.M162Wfs*114 | Frame Shift Del (DEL) | VAF 60/158 reads (38%) | catalogued as COSV51704513; called by pindel, varscan2
- DAGLB | c.457A>G p.I153V | Missense Mutation (SNP) | VAF 34/136 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs760695388, COSV51706217; called by muse, varscan2
- DAPK1 | c.3400G>A p.V1134M | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.656); catalogued as rs942463399, COSV100800792, COSV63791566; called by muse, mutect2, varscan2
- DAPK3 | c.1300G>A p.V434M | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.125); catalogued as COSV56664285; called by muse, mutect2, varscan2
- DCDC1 | c.5260G>A p.A1754T (on ENST00000597505 / NM_001367979.1; = p.A861T on NM_020869.3) | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as COSV100360459; called by muse, varscan2
- DCDC1 | c.2608G>A p.E870K | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV100338130; called by muse, mutect2
- DCLK1 | c.1577G>A p.S526N | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.665); catalogued as COSV55202975; called by muse, mutect2, varscan2
- DDR1 | c.443A>G p.E148G | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV61323972; called by muse, mutect2, varscan2
- DDR2 | c.109T>G p.S37A | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.074); catalogued as COSV63373441; called by muse, mutect2, varscan2
- DDX17 | c.362del p.K121Sfs*4 | Frame Shift Del (DEL) | VAF 8/54 reads (15%) | catalogued as rs759023106; called by mutect2, varscan2
- DDX19A | c.682A>G p.K228E | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.591); catalogued as COSV56361030; called by muse, mutect2, varscan2
- DDX27 | c.2072del p.K691Rfs*4 | Frame Shift Del (DEL) | VAF 22/108 reads (20%) | catalogued as rs766714372; called by mutect2, varscan2
- DDX53 | c.605A>G p.N202S | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.713); catalogued as COSV60069746; called by muse, mutect2, varscan2
- DDX54 | c.2081+1del p.X694_splice | Splice Site (DEL) | VAF 23/80 reads (29%) | catalogued as rs777863339; called by mutect2, pindel, varscan2
- DDX60 | c.3398del p.L1133Yfs*4 | Frame Shift Del (DEL) | VAF 13/58 reads (22%) | catalogued as rs778036194; called by mutect2, varscan2
- DECR2 | c.310T>C p.F104L | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as COSV54795918; called by muse, mutect2, varscan2
- DEF8 | c.1104+1G>A p.X368_splice | Splice Site (SNP) | VAF 5/31 reads (16%) | catalogued as rs1053825653, COSV51920731; called by muse, mutect2
- DENND1C | c.491del p.P164Lfs*29 | Frame Shift Del (DEL) | VAF 13/53 reads (25%) | catalogued as rs553532837; called by mutect2, varscan2
- DENND2A | c.1628T>C p.L543P | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV52056787; called by muse, mutect2, varscan2
- DENND4B | c.4384C>A p.L1462M | Missense Mutation (SNP) | VAF 9/125 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63411191; called by muse, mutect2
- DENND4B | c.22del p.R8Gfs*8 | Frame Shift Del (DEL) | VAF 6/25 reads (24%) | catalogued as rs755611865; called by mutect2, pindel
- DFFA | c.842A>T p.K281M | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs761386584, COSV65478050; called by muse, mutect2, varscan2
- DGKK | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.913); catalogued as COSV65709076; called by muse, mutect2, varscan2
- DHRS3 | c.830T>A p.L277H | Missense Mutation (SNP) | VAF 48/170 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV66108740; called by muse, mutect2, varscan2
- DIAPH2 | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.429); catalogued as COSV61286601; called by muse, mutect2, varscan2
- DISP2 | c.450-2A>G p.X150_splice | Splice Site (SNP) | VAF 35/189 reads (19%) | catalogued as COSV51136246; called by muse, mutect2, varscan2
- DISP3 | c.103G>T p.G35W | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.41); catalogued as COSV53834848; called by muse, mutect2, varscan2
- DISP3 | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV53834870; called by muse, mutect2
- DKK3 | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV58869805; called by muse, mutect2, varscan2
- DLC1 | c.1963G>T p.G655C (on ENST00000276297 / NM_001348081.2; = p.G218C on NM_006094.5) | Missense Mutation (SNP) | VAF 25/200 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.598); catalogued as COSV52320937; called by muse, mutect2, varscan2
- DLGAP4 | c.1135G>A p.D379N | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs975961127, COSV59421852; called by muse, mutect2, varscan2
- DLX5 | c.149C>T p.P50L | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.41); catalogued as COSV56033860; called by muse, mutect2, varscan2
- DMAP1 | c.1070C>T p.T357M | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1173638863, COSV60001541; called by muse, mutect2, varscan2
- DMD | c.3407C>A p.T1136N | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.11); PolyPhen benign (0.056); catalogued as COSV63780584; called by muse, mutect2, varscan2
- DMPK | c.1531C>T p.R511W | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.816); catalogued as rs1485626575, COSV52181229; called by muse, mutect2, varscan2
- DMRTB1 | c.19C>A p.R7S | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65113028, COSV65113762; called by muse, mutect2, varscan2
- DNAH10 | c.5092G>A p.V1698M (on ENST00000409039; = p.V1637M on NM_207437.3) | Missense Mutation (SNP) | VAF 41/146 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs369082437; called by muse, mutect2, varscan2
- DNAH10 | c.13366C>A p.L4456I (on ENST00000409039; = p.L4395I on NM_207437.3) | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.822); catalogued as COSV53021555; called by muse, mutect2, varscan2
- DNAH7 | c.1037del p.K346Sfs*23 | Frame Shift Del (DEL) | VAF 12/50 reads (24%) | catalogued as rs761292636; called by mutect2, varscan2
- DNAH8 | c.7051G>A p.V2351M | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV59471333; called by muse, mutect2, varscan2
- DNAJC1 | c.629del p.N210Mfs*5 | Frame Shift Del (DEL) | VAF 22/94 reads (23%) | catalogued as rs767116339; called by mutect2, pindel, varscan2
- DNHD1 | c.13835C>A p.P4612H | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV54439134; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 8/61 reads (13%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOCK4 | c.5836G>T p.G1946W | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.818); catalogued as COSV70241648, COSV70244602; called by muse, mutect2, varscan2
- DOCK8 | c.4606T>C p.F1536L | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as COSV66620736; called by muse, mutect2, varscan2
- DOK6 | c.800C>T p.A267V | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.211); catalogued as rs916644981, COSV66934526; called by muse, mutect2, varscan2
- DPP7 | c.1205del p.G402Vfs*28 | Frame Shift Del (DEL) | VAF 9/35 reads (26%) | catalogued as rs748560644; called by mutect2, pindel, varscan2
- DSCAM | c.1577G>A p.R526H | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs752824503, COSV68033230, COSV68034775; called by muse, mutect2, varscan2
- DTX1 | c.1601G>A p.R534H | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771660342, COSV55658850; called by muse, mutect2, varscan2
- DUOX2 | c.1982C>T p.P661L | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV66533875; called by muse, mutect2, varscan2
- DUOX2 | c.1666C>T p.Q556* | Nonsense Mutation (SNP) | VAF 55/170 reads (32%) | catalogued as rs771710411, COSV66533882; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.1060del p.W354Gfs*2 | Frame Shift Del (DEL) | VAF 8/52 reads (15%) | catalogued as rs746928635; called by pindel, varscan2
- DYNC1H1 | c.11856G>T p.Q3952H | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as COSV64140693; called by muse, mutect2, varscan2
- EBAG9 | c.628G>A p.V210M | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs776273358, COSV61753502; called by muse, mutect2, varscan2
- EBF3 | c.136G>A p.G46S | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.056); catalogued as COSV62475288; called by muse, mutect2
- EBPL | c.516del p.F172Lfs*7 | Frame Shift Del (DEL) | VAF 17/54 reads (31%) | catalogued as rs369293935; called by mutect2, varscan2
- EGR3 | c.935G>A p.R312Q | Missense Mutation (SNP) | VAF 38/210 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57833881; called by muse, mutect2, varscan2
- EHMT1 | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 37/138 reads (27%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.993); catalogued as COSV58379797; called by muse, mutect2, varscan2
- EHMT2 | c.3404G>A p.R1135H | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.749); catalogued as COSV57668709; called by muse, mutect2, varscan2
- EIF4G1 | c.2872T>C p.Y958H (on ENST00000346169 / NM_198241.3; = p.Y763H on NM_004953.5) | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59993029; called by muse, mutect2, varscan2
- ELAVL3 | c.47del p.G16Afs*35 | Frame Shift Del (DEL) | VAF 8/35 reads (23%) | catalogued as rs751148694; called by mutect2, varscan2
- ELMOD3 | c.940A>G p.K314E | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV55708477; called by muse, mutect2, varscan2
- ENC1 | c.482G>A p.C161Y | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56630688; called by muse, mutect2, varscan2
- EPB41L4A | c.1288C>T p.R430C | Missense Mutation (SNP) | VAF 38/135 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs368831750; called by muse, mutect2, varscan2
- EPB41L5 | c.802del p.W268Gfs*4 | Frame Shift Del (DEL) | VAF 7/43 reads (16%) | catalogued as rs35675992; called by mutect2, pindel, varscan2
- EPB41L5 | c.871C>T p.Q291* | Nonsense Mutation (SNP) | VAF 16/53 reads (30%) | catalogued as COSV55353186, COSV55355859; called by muse, mutect2, varscan2
- EPHA10 | c.1556T>C p.L519P | Missense Mutation (SNP) | VAF 72/245 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV57626322; called by muse, mutect2, varscan2
- EPHA2 | c.1805T>C p.L602S | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.273); catalogued as COSV64454339; called by muse, mutect2
- EPHA3 | c.602del p.K201Sfs*6 | Frame Shift Del (DEL) | VAF 31/158 reads (20%) | catalogued as COSV60725586; called by mutect2, pindel, varscan2
- EPHA5 | c.2679A>C p.E893D | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.982); catalogued as COSV56665280; called by muse, mutect2, varscan2
- EPHB2 | c.2474G>A p.R825Q (on ENST00000400191 / NM_001309193.2; = p.R826Q on NM_004442.7) | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.441); catalogued as rs758794865, COSV65861898; called by muse, mutect2, varscan2
- EPHB6 | c.165+1del | Frame Shift Del (DEL) | VAF 16/90 reads (18%) | catalogued as rs771807343; called by mutect2, pindel, varscan2
- EPHB6 | c.334C>T p.R112W | Missense Mutation (SNP) | VAF 53/224 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs548632943, COSV67417380, COSV67420686; called by muse, mutect2, varscan2
- EPHX3 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as rs1271026703, COSV54592120; called by muse, mutect2, varscan2
- EPPK1 | c.2791G>A p.A931T | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.011); catalogued as rs782304774, COSV73262243; called by muse, mutect2, varscan2
- EPS8L1 | c.1535G>A p.R512H (on ENST00000201647 / NM_133180.3; = p.R385H on NM_017729.3) | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.919); catalogued as rs370885910; called by muse, mutect2, varscan2
- ERN2 | c.466dup p.R156Pfs*15 | Frame Shift Ins (INS) | VAF 24/112 reads (21%) | catalogued as rs760310462; called by mutect2, pindel, varscan2
- ESF1 | c.1328C>T p.P443L | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs746933130, COSV52523391; called by muse, mutect2, varscan2
- EVC | c.565A>G p.S189G | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV99381615; called by muse, mutect2, varscan2
- EVI5L | c.1817C>T p.A606V | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.025); catalogued as COSV54487918; called by muse, mutect2
- EXO5 | c.980T>C p.M327T | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV56416333; called by muse, mutect2, varscan2
- EXTL3 | c.1666C>T p.R556C | Missense Mutation (SNP) | VAF 26/131 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.443); catalogued as rs755902308, COSV55039726, COSV99594063; called by muse, mutect2, varscan2
- EYA2 | c.908G>A p.R303H | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.767); catalogued as rs780109158, COSV57942494; called by muse, mutect2, varscan2
- EZHIP | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.05); catalogued as rs782321744, COSV57956911, COSV57957472; called by muse, mutect2, varscan2
- FAM120B | c.1210T>C p.C404R | Missense Mutation (SNP) | VAF 94/404 reads (23%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.804); catalogued as COSV53007116; called by muse, mutect2, varscan2
- FAM155B | c.554del p.N185Tfs*40 | Frame Shift Del (DEL) | VAF 28/44 reads (64%) | catalogued as rs749254240; called by mutect2, varscan2
- FAM166A | c.110G>A p.R37H | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs745850459, COSV61118467; called by muse, mutect2, varscan2
- FAM214B | c.124del p.A42Rfs*25 | Frame Shift Del (DEL) | VAF 15/47 reads (32%) | catalogued as rs746881923; called by mutect2, pindel, varscan2
- FAM83C | c.514-1G>T p.X172_splice | Splice Site (SNP) | VAF 30/116 reads (26%) | catalogued as COSV65584051; called by muse, mutect2, varscan2
- FAM83H | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 39/166 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs782447687, COSV66353726; called by muse, mutect2, varscan2
- FAM98C | c.934G>A p.V312I | Missense Mutation (SNP) | VAF 44/123 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.179); catalogued as rs1011014362, COSV53039545; called by muse, mutect2, varscan2
- FAT2 | c.12662G>A p.G4221D | Missense Mutation (SNP) | VAF 82/301 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.273); catalogued as COSV55826774; called by muse, mutect2, varscan2
- FAT3 | c.2294T>C p.I765T | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV53157565; called by muse, mutect2, varscan2
- FAT4 | c.13293C>A p.D4431E | Missense Mutation (SNP) | VAF 45/200 reads (23%) | SIFT tolerated, low confidence (0.65); PolyPhen possibly damaging (0.848); catalogued as COSV58702180; called by muse, mutect2, varscan2
- FBN1 | c.13C>T p.R5C | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as rs759323371, COSV57326744; called by muse, mutect2, varscan2
- FBN2 | c.1640G>T p.G547V | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52536445; called by muse, mutect2, varscan2
- FBXL7 | c.580A>G p.S194G | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as COSV61650969; called by muse, mutect2, varscan2
- FBXO21 | c.432del p.F144Lfs*9 | Frame Shift Del (DEL) | VAF 19/66 reads (29%) | catalogued as rs772635228; called by mutect2, varscan2
- FBXO6 | c.613A>G p.I205V | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.046); catalogued as COSV52418274; called by muse, mutect2, varscan2
- FDXR | c.1022G>A p.R341H (on ENST00000293195 / NM_024417.5; = p.R347H on NM_004110.6) | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as rs376509346; called by muse, mutect2, varscan2
- FER1L6 | c.3708del p.G1237Afs*10 | Frame Shift Del (DEL) | VAF 7/61 reads (11%) | catalogued as rs747094222, COSV67548414; called by mutect2, pindel, varscan2
- FERMT2 | c.455del p.K152Rfs*4 | Frame Shift Del (DEL) | VAF 14/72 reads (19%) | catalogued as rs766229731; called by mutect2, varscan2
- FES | c.619G>A p.G207S | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as rs763029771, COSV51578808; called by muse, mutect2, varscan2
- FEZF2 | c.1009C>G p.Q337E | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.185); catalogued as COSV51864162; called by muse, mutect2, varscan2
- FFAR2 | c.683T>G p.L228R | Missense Mutation (SNP) | VAF 33/141 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55833064; called by muse, mutect2, varscan2
- FGF17 | c.497G>A p.R166H | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.815); catalogued as rs866278822, COSV63925499, COSV63925793; called by muse, mutect2, varscan2
- FGF7 | c.535del p.T179Rfs*15 | Frame Shift Del (DEL) | VAF 12/34 reads (35%) | catalogued as rs777372807; called by mutect2, varscan2
- FGFR4 | c.722T>C p.V241A | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV52808111; called by muse, mutect2, varscan2
- FGFR4 | c.2246C>T p.A749V | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0.253); catalogued as rs866922351, COSV52803902; called by muse, mutect2
- FHDC1 | c.3362G>A p.R1121K | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.66); PolyPhen benign (0.007); catalogued as rs1447523709, COSV52602246; called by muse, varscan2
- FIGN | c.1970C>T p.A657V | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.903); catalogued as rs1445178845, COSV60764533; called by muse, mutect2, varscan2
- FILIP1L | c.3163A>G p.I1055V (on ENST00000354552 / NM_182909.3; = p.I815V on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/250 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.952); catalogued as rs778153475, COSV58773838; called by muse, mutect2, varscan2
- FKBP15 | c.1994del p.K665Rfs*9 | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | catalogued as rs774060142; called by mutect2, pindel, varscan2
- FLG2 | c.4025G>C p.R1342T | Missense Mutation (SNP) | VAF 63/236 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.878); catalogued as COSV66166788, COSV66171676; called by muse, mutect2, varscan2
- FLII | c.2404A>G p.K802E | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57499920; called by muse, mutect2, varscan2
- FLNA | c.4465G>A p.G1489R | Missense Mutation (SNP) | VAF 70/139 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as rs782276039, COSV61048941; called by muse, mutect2, varscan2
- FLRT2 | c.637G>A p.G213R | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs926591443, COSV58147960; called by muse, mutect2, varscan2
- FMN1 | c.3639G>T p.K1213N (on ENST00000616417 / NM_001277313.2; = p.K990N on NM_001103184.4) | Missense Mutation (SNP) | VAF 22/232 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57930588; called by muse, mutect2
- FOXD4L1 | c.53G>A p.R18Q | Missense Mutation (SNP) | VAF 45/160 reads (28%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.05); catalogued as rs900886236, COSV52076033; called by muse, mutect2, varscan2
- FOXF2 | c.302C>T p.P101L | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52526932; called by muse, mutect2, varscan2
- FOXG1 | c.1409del p.G470Dfs*18 | Frame Shift Del (DEL) | VAF 18/109 reads (17%) | catalogued as COSV57396020; called by mutect2, pindel, varscan2
- FPR1 | c.758G>A p.C253Y | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59053302; called by muse, mutect2, varscan2
- FRAT1 | c.781G>T p.G261C | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.297); catalogued as COSV100925164; called by muse, mutect2
- FRMD1 | c.439G>A p.V147M | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs151107075, COSV51960187; called by muse, mutect2, varscan2
- FRMD4A | c.3014del p.P1005Qfs*8 | Frame Shift Del (DEL) | VAF 20/129 reads (16%) | catalogued as rs752538869; called by mutect2, pindel, varscan2
- FRMPD1 | c.3118G>T p.D1040Y | Missense Mutation (SNP) | VAF 53/215 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.927); catalogued as COSV66702090; called by muse, mutect2, varscan2
- FRMPD3 | c.3016G>T p.G1006C | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.249); catalogued as COSV52188259, COSV99346161; called by muse, mutect2, varscan2
- FRY | c.439C>A p.P147T | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.241); catalogued as COSV66576514; called by muse, mutect2
- FRZB | c.386C>T p.S129L | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.17); catalogued as COSV54555586; called by muse, mutect2, varscan2
- FSTL5 | c.854A>G p.N285S | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as rs182601174; called by muse, mutect2, varscan2
- FUT10 | c.412C>T p.R138W | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756229709, COSV59449980; called by muse, mutect2, varscan2
- FYCO1 | c.2567A>G p.Q856R | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV56118630; called by muse, mutect2, varscan2
- FZD7 | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV53811191; called by muse, mutect2, varscan2
- FZD8 | c.802T>C p.F268L | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.147); catalogued as rs1416205284, COSV65968148; called by muse, mutect2, varscan2
- GAGE1 | c.400C>A p.L134I | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.094); catalogued as rs199853455, COSV67747851; called by muse, mutect2, varscan2
- GAK | c.1603G>A p.A535T | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as rs752168895, COSV58508292; called by muse, mutect2, varscan2
- GAL3ST2 | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as COSV51951283; called by muse, mutect2, varscan2
- GANC | c.2509T>G p.C837G | Missense Mutation (SNP) | VAF 36/124 reads (29%) | PolyPhen benign (0); catalogued as COSV58810979; called by muse, mutect2, varscan2
- GART | c.2420del p.K807Rfs*7 | Frame Shift Del (DEL) | VAF 16/48 reads (33%) | catalogued as rs758551787; called by mutect2, varscan2
- GAS2L2 | c.1027C>T p.P343S | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT tolerated (0.45); PolyPhen benign (0.011); catalogued as rs1555599078; called by muse, mutect2, varscan2
- GAS8 | c.232C>T p.R78W | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs768149188, COSV51945532; called by muse, mutect2, varscan2
- GATA3 | c.708del p.S237Afs*28 | Frame Shift Del (DEL) | VAF 24/104 reads (23%) | catalogued as rs771019738, COSV60522496; called by mutect2, pindel, varscan2
- GBP7 | c.1293dup p.H432Afs*12 | Frame Shift Ins (INS) | VAF 38/136 reads (28%) | catalogued as rs754177800; called by mutect2, varscan2
- GDA | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 48/190 reads (25%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs1362245484, COSV52996561; called by muse, mutect2, varscan2
- GDF15 | c.573del p.R192Afs*46 | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | catalogued as rs1254999181; called by mutect2, pindel, varscan2
- GDF5 | c.1159C>T p.R387C | Missense Mutation (SNP) | VAF 74/258 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs139413270; called by muse, mutect2, varscan2
- GFM1 | c.266T>C p.M89T | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51834953; called by muse, mutect2, varscan2
- GGN | c.1538C>T p.A513V | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.019); catalogued as rs761627725, COSV53057065; called by mutect2, varscan2
- GJA3 | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs781023239, COSV53834771; called by muse, mutect2, varscan2
- GJB4 | c.211G>A p.V71M | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); catalogued as rs370587030; called by muse, mutect2, varscan2
- GJB4 | c.479G>T p.R160L | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.091); catalogued as COSV58356277, COSV58356883; called by muse, mutect2, varscan2
- GJD4 | c.621_622del p.S208Ffs*44 | Frame Shift Del (DEL) | VAF 5/32 reads (16%) | catalogued as rs768263111; called by mutect2, pindel, varscan2
- GLB1L3 | c.1009A>G p.N337D | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101111035, COSV66282851; called by muse, mutect2, varscan2
- GLIS3 | c.1135T>C p.F379L | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60933756; called by muse, mutect2
- GLRB | c.880G>A p.A294T | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs1560967306, COSV52415127; called by muse, mutect2, varscan2
- GNAI3 | c.83A>G p.E28G | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.529); catalogued as COSV63984300; called by muse, mutect2, varscan2
- GOLGA2 | c.2929del p.Y977Tfs*9 | Frame Shift Del (DEL) | VAF 57/216 reads (26%) | catalogued as rs763679060; called by mutect2, varscan2
- GOLGA4 | c.468del p.K156Nfs*23 | Frame Shift Del (DEL) | VAF 20/79 reads (25%) | catalogued as rs769624935; called by mutect2, pindel, varscan2
- GOT1L1 | c.1243del p.T415Hfs*2 | Frame Shift Del (DEL) | VAF 16/82 reads (20%) | catalogued as rs370114090; called by mutect2, varscan2
- GP2 | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765756297, COSV56895921; called by muse, mutect2, varscan2
- GPC3 | c.362A>G p.H121R | Missense Mutation (SNP) | VAF 32/60 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0.18); catalogued as rs1185826089, COSV63669815; called by muse, mutect2, varscan2
- GPC6 | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1357289814, COSV65494787, COSV65525111; called by muse, mutect2, varscan2
- GPR137 | c.403G>A p.G135S | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.634); catalogued as rs1343581451, COSV57403513; called by muse, mutect2, varscan2
- GPR156 | c.1097A>G p.N366S | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1443757791, COSV59941856; called by muse, mutect2, varscan2
- GRAMD1A | c.2135C>T p.P712L | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as COSV52895260; called by muse, mutect2, varscan2
- GRIK2 | c.2546del p.N849Tfs*14 | Frame Shift Del (DEL) | VAF 50/110 reads (45%) | catalogued as rs760757380; called by mutect2, varscan2
- GRIN1 | c.1465C>T p.R489W | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); catalogued as COSV59299586; called by muse, mutect2
- GSTK1 | c.373G>A p.V125I | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs757110852, COSV64424292; called by mutect2, varscan2
- GSTT2B | c.538G>A p.G180S | Missense Mutation (SNP) | VAF 23/145 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.698); catalogued as rs959310838; called by muse, mutect2, varscan2
- GTF3C1 | c.2299del p.S767Vfs*7 | Frame Shift Del (DEL) | VAF 22/83 reads (27%) | catalogued as rs1231771183; called by mutect2, pindel, varscan2
- GTF3C4 | c.578T>C p.I193T | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.329); catalogued as COSV64645883; called by muse, mutect2, varscan2
- GUCY2C | c.1928del p.K643Rfs*41 | Frame Shift Del (DEL) | VAF 24/110 reads (22%) | catalogued as COSV53786951; called by mutect2, pindel, varscan2
- HABP4 | c.453C>A p.Y151* | Nonsense Mutation (SNP) | VAF 32/121 reads (26%) | catalogued as COSV64515147; called by muse, mutect2, varscan2
- HAPLN1 | c.352A>C p.S118R | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0.024); catalogued as COSV57150950; called by muse, mutect2, varscan2
- HARS1 | c.796C>T p.R266C | Missense Mutation (SNP) | VAF 39/155 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.677); catalogued as rs575673293, COSV56905380; called by muse, mutect2, varscan2
- HAS1 | c.1690C>T p.R564W | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as rs778353426, COSV55789131; called by muse, mutect2
- HCN2 | c.1945C>T p.R649W | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52114644; called by muse, mutect2, varscan2
- HDGFL2 | c.1498C>A p.L500I | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV56684483; called by muse, mutect2, varscan2
- HEATR5B | c.6214del p.*2072Nfs*3 | Frame Shift Del (DEL) | VAF 10/30 reads (33%) | catalogued as rs1315552549, COSV51848615; called by mutect2, varscan2
- HEATR5B | c.1708G>A p.V570I | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.275); catalogued as rs778523774, COSV51857165; called by muse, mutect2, varscan2
- HECTD2 | c.1144del p.I382Sfs*11 | Frame Shift Del (DEL) | VAF 18/76 reads (24%) | catalogued as rs57105282; called by mutect2, varscan2
- HELLS | c.1840del p.R614Efs*11 | Frame Shift Del (DEL) | VAF 10/50 reads (20%) | catalogued as rs745837238; called by mutect2, varscan2
- HEPH | c.2533A>G p.T845A (on ENST00000343002; = p.T578A on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV57963914, COSV57969671; called by muse, mutect2, varscan2
- HERC2 | c.13589G>A p.S4530N | Missense Mutation (SNP) | VAF 33/141 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV55342918; called by muse, mutect2, varscan2
- HGFAC | c.1433G>A p.G478D | Missense Mutation (SNP) | VAF 124/463 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as COSV66977256; called by muse, mutect2, varscan2
- HIC1 | c.1501G>A p.G501R (on ENST00000322941 / NM_001098202.1; = p.G482R on NM_006497.4) | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as rs771684583, COSV53973255; called by muse, mutect2, varscan2
- HINFP | c.1184G>A p.R395H | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as rs1249743832, COSV63432524; called by muse, mutect2, varscan2
- HIP1R | c.326G>A p.R109H | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.262); catalogued as rs1205862978, COSV53443888; called by muse, mutect2, varscan2
- HIVEP1 | c.1620T>A p.N540K | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.026); catalogued as COSV65104143; called by muse, mutect2, varscan2
- HIVEP2 | c.4318C>T p.R1440* | Nonsense Mutation (SNP) | VAF 30/99 reads (30%) | catalogued as COSV50039603; called by muse, mutect2, varscan2
- HMMR | c.1998del p.K666Nfs*11 | Frame Shift Del (DEL) | VAF 17/59 reads (29%) | catalogued as rs761272507; called by mutect2, varscan2
- HOMER2 | c.587G>A p.R196Q (on ENST00000304231 / NM_199330.3; = p.R185Q on NM_004839.4) | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.113); catalogued as rs864309524, CM152859, COSV58487922; called by muse, mutect2, varscan2
- HOOK3 | c.707C>A p.P236H | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV56886232; called by muse, mutect2, varscan2
- HOXA9 | c.274G>A p.V92M | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.33); PolyPhen benign (0.072); catalogued as COSV58656524; called by muse, mutect2, varscan2
- HOXD3 | c.1003G>A p.E335K | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as rs1218861940, COSV50884160; called by muse, mutect2, varscan2
- HS6ST1 | c.1192G>A p.V398M | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.017); catalogued as rs374958226; called by muse, mutect2, varscan2
- HS6ST2 | c.1201G>T p.G401C | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63716912; called by muse, mutect2, varscan2
- HTR6 | c.310G>A p.A104T | Missense Mutation (SNP) | VAF 39/149 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.588); catalogued as COSV57034214; called by muse, mutect2, varscan2
- HTT | c.7207C>G p.P2403A | Missense Mutation (SNP) | VAF 19/142 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61860571; called by muse, mutect2, varscan2
- IARS1 | c.1156C>T p.R386* | Nonsense Mutation (SNP) | VAF 29/113 reads (26%) | catalogued as rs140292751; called by muse, mutect2, varscan2
- IFNAR2 | c.353C>T p.T118M | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.348); catalogued as rs752913293, COSV59750553; called by muse, mutect2, varscan2
- IFT88 | c.136G>T p.A46S (on ENST00000319980 / NM_001318493.2; = p.A37S on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.77); PolyPhen benign (0.042); catalogued as COSV60676130; called by muse, mutect2, varscan2
- IGF2BP1 | c.1565T>C p.V522A | Missense Mutation (SNP) | VAF 7/150 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); catalogued as COSV51734627; called by muse, mutect2
- IGF2R | c.3949del p.D1317Tfs*27 | Frame Shift Del (DEL) | VAF 58/220 reads (26%) | catalogued as rs760021495; called by mutect2, varscan2
- IGHM | c.890C>T p.S297F | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as rs1555378040; called by muse, mutect2, varscan2
- IKBKB | c.387T>C p.I129= | Splice Region (SNP) | VAF 19/101 reads (19%) | catalogued as COSV60599151; called by muse, mutect2, varscan2
- INCENP | c.763T>C p.S255P | Missense Mutation (SNP) | VAF 44/155 reads (28%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.598); catalogued as COSV53919530; called by muse, mutect2, varscan2
- INTS3 | c.1766+1G>A p.X589_splice | Splice Site (SNP) | VAF 17/118 reads (14%) | catalogued as COSV59680659; called by muse, mutect2, varscan2
- IPO4 | c.398C>T p.P133L | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV55781368; called by muse, mutect2, varscan2
- IQGAP1 | c.2540G>A p.R847Q | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1314271863, COSV51589549; called by muse, mutect2, varscan2
- IQSEC1 | c.944del p.P315Lfs*218 | Frame Shift Del (DEL) | VAF 34/135 reads (25%) | catalogued as COSV99832030; called by mutect2, pindel, varscan2
- IQUB | c.1861C>T p.R621C | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.528); catalogued as rs765950092, COSV100227178, COSV61241693; called by muse, mutect2, varscan2
- IRAK3 | c.1461C>A p.N487K | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.94); PolyPhen benign (0.011); catalogued as CD1513356, COSV54164513; called by muse, mutect2, varscan2
- IRS2 | c.3895G>A p.V1299I | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs1019316102, COSV65477374, COSV65480353; called by muse, mutect2
- IRX4 | c.875C>T p.A292V | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs775564077, COSV99180767; called by muse, mutect2
- IRX6 | c.37G>A p.A13T | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.43); PolyPhen benign (0.022); catalogued as rs768272784, COSV51861730; called by muse, mutect2, varscan2
- ISM1 | c.1235C>T p.A412V | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1480185372, COSV52606362; called by muse, mutect2, varscan2
- ITGA7 | c.1190del p.G397Vfs*7 (on ENST00000555728; = p.G353Vfs*7 on NM_002206.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 30/147 reads (20%) | catalogued as rs1361836055; called by mutect2, pindel, varscan2
- ITGA8 | c.301G>T p.E101* | Nonsense Mutation (SNP) | VAF 42/203 reads (21%) | catalogued as COSV65234000; called by muse, mutect2, varscan2
- ITIH2 | c.1678G>T p.A560S | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.035); catalogued as COSV64434677; called by muse, mutect2, varscan2
- ITPR1 | c.2813G>A p.R938Q (on ENST00000354582; = p.R923Q on NM_002222.7) | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.997); catalogued as rs749154645, COSV56975177; called by muse, mutect2, varscan2
- ITSN2 | c.1784T>G p.L595R | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV61952277; called by muse, mutect2, varscan2
- JAG1 | c.3289C>T p.R1097W | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768554175, HM080117, COSV54761313; ClinVar: uncertain significance; called by mutect2, varscan2
- JARID2 | c.3172A>G p.M1058V | Missense Mutation (SNP) | VAF 65/241 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.024); catalogued as COSV59195544; called by muse, mutect2, varscan2
- JPH1 | c.227C>T p.T76M | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV60613759; called by muse, mutect2, varscan2
- JSRP1 | c.53G>A p.C18Y | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs200818695, COSV55560201; called by muse, mutect2, varscan2
- KALRN | c.5390G>A p.R1797Q (on ENST00000360013 / NM_001024660.4; = p.R100Q on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/171 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.396); catalogued as rs201792111; called by muse, mutect2, varscan2
- KALRN | c.8375A>G p.Q2792R (on ENST00000360013 / NM_001024660.4; = p.Q1095R on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.98); catalogued as COSV52262403; called by muse, mutect2, varscan2
- KANK4 | c.2319+2T>C p.X773_splice | Splice Site (SNP) | VAF 22/98 reads (22%) | catalogued as COSV58093790; called by muse, mutect2, varscan2
- KANSL1 | c.260T>C p.V87A | Missense Mutation (SNP) | VAF 36/119 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV52269606; called by muse, mutect2, varscan2
- KATNIP | c.3931C>T p.R1311C | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs749404725, COSV55187384; called by muse, mutect2, varscan2
- KCNH1 | c.545C>A p.S182Y | Missense Mutation (SNP) | VAF 37/142 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.099); catalogued as COSV55096316; called by muse, mutect2, varscan2
- KCNH3 | c.2123del p.G708Efs*11 | Frame Shift Del (DEL) | VAF 18/103 reads (17%) | catalogued as rs1229306184; called by mutect2, pindel, varscan2
- KCNH8 | c.2352dup p.N785Qfs*3 | Frame Shift Ins (INS) | VAF 27/107 reads (25%) | catalogued as rs760381227; called by mutect2, varscan2
- KCNJ4 | c.59G>A p.R20H | Missense Mutation (SNP) | VAF 121/476 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV57858276, COSV57859033; called by muse, mutect2, varscan2
- KCNJ6 | c.827C>T p.P276L | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55710318; called by muse, mutect2, varscan2
- KCNK13 | c.1171dup p.V391Gfs*67 | Frame Shift Ins (INS) | VAF 10/47 reads (21%) | catalogued as rs766469179; called by mutect2, varscan2
- KCNRG | c.275G>A p.R92H | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT tolerated (0.58); PolyPhen benign (0.074); catalogued as rs200474686; called by muse, mutect2, varscan2
- KDELR1 | c.193-1G>A p.X65_splice | Splice Site (SNP) | VAF 19/72 reads (26%) | catalogued as COSV58102705; called by muse, mutect2, varscan2
- KDM4D | c.278del p.K93Rfs*4 | Frame Shift Del (DEL) | VAF 32/122 reads (26%) | catalogued as rs142280183; called by mutect2, varscan2
- KDR | c.3125T>C p.V1042A | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55772436, COSV55773060; called by muse, mutect2, varscan2
- KIAA1217 | c.214C>G p.P72A | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs754656050, COSV64601592, COSV64611067; called by muse, mutect2, varscan2
- KIAA1614 | c.2087C>T p.T696M | Missense Mutation (SNP) | VAF 43/198 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as rs566865809, COSV62551530; called by muse, mutect2, varscan2
- KIF14 | c.4927A>G p.S1643G | Missense Mutation (SNP) | VAF 38/151 reads (25%) | SIFT tolerated (0.45); PolyPhen benign (0.039); catalogued as COSV66263380; called by muse, mutect2, varscan2
- KIF14 | c.1694A>T p.D565V | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV66263388; called by muse, mutect2, varscan2
- KIF20B | c.1758del p.K586Nfs*2 | Frame Shift Del (DEL) | VAF 10/42 reads (24%) | catalogued as rs753332734; called by mutect2, varscan2
- KLF4 | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs781269132, COSV65928709; called by muse, mutect2, varscan2
- KLHL14 | c.227A>G p.D76G | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV63834726; called by muse, mutect2, varscan2
- KLHL17 | c.1439C>T p.T480M | Missense Mutation (SNP) | VAF 63/183 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.035); catalogued as rs780498394, COSV58530964; called by muse, mutect2, varscan2
- KLHL4 | c.1693G>A p.V565I | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV64146401; called by muse, mutect2, varscan2
- KLK13 | c.551G>A p.R184H | Missense Mutation (SNP) | VAF 57/233 reads (24%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.86); catalogued as rs776990347, COSV50067343, COSV50067386; called by muse, mutect2, varscan2
- KLK4 | c.248T>C p.L83P | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as COSV60676940; called by muse, mutect2
- KMT2A | c.11462G>A p.R3821Q | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as COSV63290668; called by muse, varscan2
- KMT2B | c.5730del p.R1911Dfs*23 | Frame Shift Del (DEL) | VAF 8/31 reads (26%) | catalogued as COSV55867385; called by mutect2, pindel, varscan2
- KMT2B | c.7427C>T p.A2476V | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.61); PolyPhen benign (0.033); catalogued as COSV55821350; called by muse, mutect2
- KMT2D | c.7220C>A p.P2407H | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV56473343; called by muse, mutect2, varscan2
- KNL1 | c.4316T>C p.M1439T (on ENST00000346991 / NM_170589.5; = p.M1413T on NM_144508.5) | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.106); catalogued as COSV61158901; called by muse, mutect2, varscan2
- KRT1 | c.1046G>A p.S349N | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs769968882, COSV52868605; called by muse, mutect2, varscan2
- KRT3 | c.467G>A p.G156D | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.826); catalogued as rs748734269, COSV58816739; called by muse, mutect2
- KRTAP10-4 | c.787T>C p.S263P | Missense Mutation (SNP) | VAF 79/291 reads (27%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV59974561; called by muse, mutect2, varscan2
- KRTAP5-7 | c.482G>C p.C161S | Missense Mutation (SNP) | VAF 91/301 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.014); catalogued as COSV68325519; called by muse, varscan2
- KSR2 | c.1919T>C p.L640P | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV56680436; called by muse, mutect2, varscan2
- LARP4B | c.1792C>T p.R598* | Nonsense Mutation (SNP) | VAF 18/82 reads (22%) | catalogued as COSV60223043; called by muse, mutect2, varscan2
- LAT | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.638); catalogued as COSV57956129; called by muse, mutect2, varscan2
- LCLAT1 | c.256G>T p.A86S | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.061); catalogued as COSV58376965; called by muse, mutect2, varscan2
- LENG1 | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 34/148 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs377766733, COSV55366816; called by muse, mutect2, varscan2
- LGR5 | c.1876C>T p.R626* | Nonsense Mutation (SNP) | VAF 31/106 reads (29%) | catalogued as rs780252667, COSV57008615; called by muse, mutect2, varscan2
- LGR6 | c.691G>A p.E231K (on ENST00000367278 / NM_001017403.1; = p.E179K on NM_021636.3) | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.817); catalogued as rs546447981, COSV55164040; called by muse, mutect2, varscan2
- LINC02210-CRHR1 | c.119C>T p.T40I | Missense Mutation (SNP) | VAF 12/256 reads (5%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.733); catalogued as COSV53284006; called by muse, mutect2
- LINGO1 | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV62436414; called by muse, mutect2
- LIPT1 | c.368del p.K123Sfs*8 | Frame Shift Del (DEL) | VAF 20/54 reads (37%) | catalogued as rs780042765; called by mutect2, varscan2
- LLGL2 | c.316G>T p.G106C | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.353); catalogued as COSV51389847; called by muse, mutect2, varscan2
- LOXL2 | c.2276del p.K759Sfs*9 | Frame Shift Del (DEL) | VAF 6/43 reads (14%) | catalogued as rs765428971; called by mutect2, pindel
- LPO | c.1837G>A p.A613T | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.25); catalogued as COSV51861596; called by muse, mutect2, varscan2
- LRFN5 | c.272C>T p.T91I | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.326); catalogued as COSV53270149, COSV99982998; called by muse, mutect2, varscan2
- LRP1B | c.10436A>G p.H3479R | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.741); catalogued as rs780006737, COSV67259710; called by muse, mutect2, varscan2
- LRP1B | c.4004C>T p.A1335V | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67259711; called by muse, mutect2, varscan2
- LRP2 | c.10651C>T p.R3551C | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1188450012, COSV55567967; called by muse, mutect2, varscan2
- LRP2 | c.5152C>T p.Q1718* | Nonsense Mutation (SNP) | VAF 21/71 reads (30%) | catalogued as COSV55567977; called by muse, mutect2, varscan2
- LRRC31 | c.254del p.K85Rfs*7 | Frame Shift Del (DEL) | VAF 46/170 reads (27%) | catalogued as rs34511323; called by mutect2, pindel, varscan2
- LRRC36 | c.2129C>A p.P710H | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV52081538; called by muse, mutect2, varscan2
- LRRC40 | c.212C>T p.S71L | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.311); catalogued as rs1328427877, COSV63941529; called by muse, mutect2, varscan2
- LRRC52 | c.580G>A p.D194N | Missense Mutation (SNP) | VAF 38/183 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.131); catalogued as COSV54233328; called by muse, mutect2, varscan2
- LRRCC1 | c.2330-1G>T p.X777_splice | Splice Site (SNP) | VAF 9/71 reads (13%) | catalogued as COSV64483046, COSV64485104; called by muse, mutect2
- LRRN3 | c.825A>G p.I275M | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV57822815; called by muse, mutect2, varscan2
- LRRTM3 | c.406C>T p.R136W | Missense Mutation (SNP) | VAF 51/168 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63670197; called by muse, mutect2, varscan2
- LRRTM4 | c.1466A>G p.K489R | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.724); catalogued as rs1432995596, COSV69141475; called by muse, mutect2, varscan2
- LTN1 | c.3934del p.S1312Pfs*13 | Frame Shift Del (DEL) | VAF 10/69 reads (14%) | catalogued as rs1568836342; called by mutect2, pindel, varscan2
- LYG2 | c.487T>A p.F163I | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs916224882, COSV60716445; called by muse, mutect2, varscan2
- LYPLAL1 | c.121A>G p.I41V | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.47); PolyPhen benign (0.019); catalogued as COSV65107021; called by muse, mutect2, varscan2
- MAB21L1 | c.674C>T p.A225V | Missense Mutation (SNP) | VAF 42/136 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.019); catalogued as COSV59811985; called by muse, mutect2, varscan2
- MACF1 | c.2870T>G p.L957R | Missense Mutation (SNP) | VAF 21/77 reads (27%) | catalogued as COSV58394462; called by muse, mutect2, varscan2
- MACROH2A2 | c.438dup p.K147Efs*21 | Frame Shift Ins (INS) | VAF 14/75 reads (19%) | catalogued as rs775088830; called by mutect2, varscan2
- MAEA | c.710G>A p.R237H (on ENST00000303400 / NM_001017405.3; = p.R196H on NM_005882.5) | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.879); catalogued as rs1463564323, COSV53262434; called by muse, mutect2, varscan2
- MAGEC3 | c.134del p.K45Rfs*15 | Frame Shift Del (DEL) | VAF 8/51 reads (16%) | catalogued as rs1281321536; called by pindel, varscan2
- MAGED1 | c.529C>T p.P177S | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.626); catalogued as COSV58516405; called by muse, mutect2, varscan2
- MAGED1 | c.1749G>A p.W583* | Nonsense Mutation (SNP) | VAF 35/58 reads (60%) | catalogued as COSV100431871, COSV58516414; called by muse, mutect2, varscan2
- MAN2B2 | c.1253A>G p.Q418R | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV53455851; called by muse, mutect2, varscan2
- MAN2C1 | c.1567T>C p.Y523H | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs372893910; called by muse, mutect2, varscan2
- MAP2K7 | c.875del p.P292Qfs*119 | Frame Shift Del (DEL) | VAF 34/135 reads (25%) | catalogued as COSV67608111; called by pindel, varscan2
- MAP3K4 | c.1092A>G p.I364M | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.028); catalogued as COSV62336966; called by muse, mutect2, varscan2
- MAP3K6 | c.2544del p.F849Sfs*143 | Frame Shift Del (DEL) | VAF 26/105 reads (25%) | catalogued as rs34008139, CD1410625; called by mutect2, pindel, varscan2
- MAP9 | c.1700del p.K567Rfs*13 | Frame Shift Del (DEL) | VAF 8/27 reads (30%) | catalogued as rs1215313075; called by mutect2, varscan2
- MAPK11 | c.557G>A p.R186H | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.499); catalogued as COSV57997821; called by muse, mutect2, varscan2
- MAPKBP1 | c.1766C>T p.A589V (on ENST00000456763 / NM_001128608.2; = p.A583V on NM_014994.3) | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52965989; called by muse, mutect2, varscan2
- MAT1A | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64746697; called by muse, mutect2, varscan2
- MBD5 | c.3383C>T p.A1128V | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV68698581; called by muse, mutect2, varscan2
- MCCC2 | c.1217-1G>T p.X406_splice | Splice Site (SNP) | VAF 20/103 reads (19%) | catalogued as COSV60156287; called by muse, mutect2, varscan2
- MCPH1 | c.2312dup p.V772Sfs*6 | Frame Shift Ins (INS) | VAF 17/135 reads (13%) | catalogued as rs1401112399; called by mutect2, pindel, varscan2
- MDN1 | c.11567A>G p.Q3856R | Missense Mutation (SNP) | VAF 39/135 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV65527988; called by muse, mutect2, varscan2
- MDN1 | c.4553T>C p.L1518P | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs752887143, COSV65527995; called by muse, mutect2, varscan2
- MED23 | c.2103del p.F701Lfs*20 | Frame Shift Del (DEL) | VAF 10/39 reads (26%) | catalogued as rs1419084791; called by mutect2, pindel, varscan2
- MED26 | c.1199G>A p.R400Q | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.161); catalogued as rs185281264, COSV54662075, COSV54662253; called by muse, mutect2, varscan2
- MED29 | c.44C>T p.P15L | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.375); catalogued as rs372207740; called by muse, mutect2, varscan2
- MEDAG | c.206del p.G69Afs*29 | Frame Shift Del (DEL) | VAF 10/20 reads (50%) | catalogued as rs745558596; called by mutect2, varscan2
- MEGF11 | c.2903C>T p.P968L | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV56558310; called by muse, mutect2, varscan2
- MESD | c.632del p.K211Rfs*6 | Frame Shift Del (DEL) | VAF 15/74 reads (20%) | catalogued as rs745891632; called by mutect2, varscan2
- METTL15 | c.189A>T p.R63S | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV57722749; called by muse, mutect2, varscan2
- MICALL1 | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs777153477, COSV53242678; called by muse, mutect2, varscan2
- MICU3 | c.1279A>G p.R427G | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV58848088; called by muse, mutect2, varscan2
- MINAR1 | c.2104del p.S702Afs*11 | Frame Shift Del (DEL) | VAF 47/196 reads (24%) | catalogued as rs748072217, COSV59581461; called by mutect2, varscan2
- MISP | c.1694G>A p.R565Q | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs141415846; called by muse, mutect2, varscan2
- MKI67 | c.4657G>A p.A1553T | Missense Mutation (SNP) | VAF 84/302 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.442); catalogued as rs371337191, COSV64076538; called by muse, mutect2, varscan2
- MLH3 | c.1755del p.E586Nfs*24 | Frame Shift Del (DEL) | VAF 33/65 reads (51%) | catalogued as rs751465048; called by mutect2, varscan2
- MMP17 | c.464C>T p.T155M | Missense Mutation (SNP) | VAF 34/183 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.455); catalogued as rs376422502, COSV99053584; called by muse, mutect2, varscan2
- MMP28 | c.1113dup p.N372Qfs*3 | Frame Shift Ins (INS) | VAF 5/25 reads (20%) | catalogued as rs750644158; called by mutect2, pindel, varscan2
- MMP8 | c.217A>C p.N73H | Missense Mutation (SNP) | VAF 34/155 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as rs753882335, COSV52633948; called by muse, mutect2, varscan2
- MN1 | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.406); catalogued as COSV56561012; called by muse, mutect2, varscan2
- MOCS3 | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 38/153 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.435); catalogued as COSV54865714; called by muse, mutect2, varscan2
- MOK | c.313del p.I105Lfs*25 | Frame Shift Del (DEL) | VAF 10/40 reads (25%) | catalogued as rs753079987; called by mutect2, varscan2
- MON1B | c.1231C>T p.R411W | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs2232507; called by muse, mutect2, varscan2
- MOXD1 | c.403A>C p.S135R | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as COSV60947556; called by muse, mutect2, varscan2
- MPP5 | c.518T>C p.M173T | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs146408908; called by muse, mutect2, varscan2
- MPRIP | c.2210A>C p.K737T | Missense Mutation (SNP) | VAF 8/182 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.878); catalogued as COSV57929585; called by muse, mutect2
- MRPL22 | c.461G>A p.G154D | Missense Mutation (SNP) | VAF 35/157 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.548); catalogued as COSV54559179; called by muse, mutect2, varscan2
- MSH6 | c.1189T>C p.Y397H | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as rs587779913, COSV52285290; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MST1 | c.1421del p.P474Qfs*52 | Frame Shift Del (DEL) | VAF 9/71 reads (13%) | catalogued as rs747477010; called by mutect2, pindel, varscan2
- MTCL1 | c.1594G>A p.E532K (on ENST00000306329 / NM_001378206.1; = p.E172K on NM_015210.4) | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.45); catalogued as rs116313795, COSV60410096; called by muse, mutect2, varscan2
- MTCL1 | c.2534G>A p.R845Q (on ENST00000306329 / NM_001378206.1; = p.R485Q on NM_015210.4) | Missense Mutation (SNP) | VAF 42/147 reads (29%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs563230567, COSV60410103; called by muse, mutect2, varscan2
- MTREX | c.2864A>G p.E955G | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as COSV57929049; called by muse, mutect2, varscan2
- MTUS1 | c.1277T>C p.M426T | Missense Mutation (SNP) | VAF 35/154 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV100029321; called by muse, mutect2, varscan2
- MUC17 | c.9875C>T p.T3292M | Missense Mutation (SNP) | VAF 156/645 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.865); catalogued as rs370607705; called by muse, mutect2, varscan2
- MUC4 | c.14497A>G p.T4833A (on ENST00000463781 / NM_018406.7; = p.T597A on NM_004532.6) | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV57796927; called by muse, mutect2, varscan2
- MUC6 | c.6387_6389del p.S2130del | In Frame Del (DEL) | VAF 14/43 reads (33%) | catalogued as rs765184193; called by pindel, varscan2
- MUTYH | c.403C>A p.Q135K | Missense Mutation (SNP) | VAF 49/203 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58344818; called by muse, mutect2, varscan2
- MYBBP1A | c.3851A>G p.K1284R | Missense Mutation (SNP) | VAF 102/355 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.476); catalogued as COSV54601787; called by muse, mutect2, varscan2
- MYCBP2 | c.4102A>G p.I1368V (on ENST00000357337; = p.I1406V on NM_015057.5) | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.558); catalogued as rs1388086817, COSV62033749; called by muse, mutect2, varscan2
- MYCBP2 | c.3661G>A p.D1221N (on ENST00000357337; = p.D1259N on NM_015057.5) | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1248391112, COSV62033769; called by muse, mutect2, varscan2
- MYH1 | c.3779T>G p.L1260R | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); catalogued as rs1179607562, COSV56854621, COSV56854791; called by muse, mutect2, varscan2
- MYH10 | c.4187A>G p.K1396R | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0.051); catalogued as COSV52607972; called by muse, mutect2, varscan2
- MYH11 | c.4045C>T p.Q1349* | Nonsense Mutation (SNP) | VAF 60/236 reads (25%) | catalogued as COSV55564730; called by muse, mutect2, varscan2
- MYH6 | c.4135A>G p.T1379A | Missense Mutation (SNP) | VAF 40/148 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.812); catalogued as COSV62453490; called by muse, mutect2, varscan2
- MYO16 | c.2525del p.F842Sfs*17 | Frame Shift Del (DEL) | VAF 14/58 reads (24%) | catalogued as rs761471964; called by mutect2, varscan2
- MYO1F | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs369105985; called by muse, mutect2, varscan2
- MYO5C | c.5011A>G p.N1671D | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV55900662; called by muse, mutect2
- MYOCD | c.890T>G p.L297R | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58509484; called by muse, varscan2
- MYOM2 | c.2375G>A p.G792D | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50753299; called by muse, mutect2, varscan2
- MYORG | c.431A>G p.H144R | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV52628107; called by muse, mutect2, varscan2
- NAALADL2 | c.931C>T p.L311F | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.659); catalogued as rs1310211173, COSV69159232; called by muse, mutect2, varscan2
- NAIF1 | c.331G>A p.G111S | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs1457940427, COSV66091970; called by muse, mutect2, varscan2
- NAV2 | c.7078G>A p.D2360N (on ENST00000396087 / NM_001244963.2; = p.D2301N on NM_145117.5) | Missense Mutation (SNP) | VAF 114/415 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60658698; called by muse, mutect2, varscan2
- NCOA1 | c.985A>G p.R329G | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); catalogued as COSV56050852; called by muse, mutect2, varscan2
- NCOR1 | c.4454C>A p.P1485H | Missense Mutation (SNP) | VAF 60/280 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51989584; called by muse, varscan2
- NDN | c.487A>G p.M163V | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.687); catalogued as COSV59361007; called by muse, mutect2, varscan2
- NDUFA10 | c.604dup p.H202Pfs*25 | Frame Shift Ins (INS) | VAF 34/114 reads (30%) | catalogued as rs746019378; ClinVar: uncertain significance; called by mutect2, varscan2
- NDUFAF3 | c.548C>T p.A183V | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.031); catalogued as rs1158260049, COSV58246865; called by muse, mutect2, varscan2
- NDUFB4 | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 19/204 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51742731; called by muse, mutect2
- NDUFS7 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs925024040, COSV52040723; called by muse, varscan2
- NEB | c.598G>A p.A200T | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.997); catalogued as rs116678485, COSV51446818; called by muse, mutect2, varscan2
- NEFL | c.1270T>C p.Y424H | Missense Mutation (SNP) | VAF 33/135 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.73); catalogued as rs570772656, COSV55338092; called by muse, mutect2, varscan2
- NEFL | c.718T>C p.Y240H | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.852); catalogued as COSV55338099; called by muse, mutect2, varscan2
- NEURL1 | c.1234A>G p.S412G | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.97); catalogued as COSV63915360; called by muse, mutect2
- NFATC2 | c.12del p.E5Sfs*35 | Frame Shift Del (DEL) | VAF 9/20 reads (45%) | catalogued as COSV101043951, COSV65356286; called by mutect2, varscan2
- NFATC4 | c.1342G>A p.G448S | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); catalogued as rs756073934, COSV51605676, COSV51608598; called by muse, mutect2, varscan2
- NFE2 | c.554T>C p.M185T | Missense Mutation (SNP) | VAF 37/141 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV56456819; called by muse, mutect2, varscan2
- NFIC | c.223C>T p.R75W | Missense Mutation (SNP) | VAF 61/168 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs751328600, COSV59415522; called by muse, mutect2, varscan2
- NFYC | c.1306G>A p.A436T (on ENST00000308733 / NM_001308114.1; = p.A313T on NM_014223.5) | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.001); catalogued as rs768809484, COSV58128475; called by muse, mutect2, varscan2
- NKX2-1 | c.598C>A p.L200M | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61389887; called by muse, mutect2, varscan2
- NKX3-1 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 66/275 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66512522; called by muse, mutect2, varscan2
- NLRC5 | c.109C>T p.P37S | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1307232274, COSV52660829; called by muse, mutect2, varscan2
- NLRC5 | c.3987-2A>G p.X1329_splice | Splice Site (SNP) | VAF 16/60 reads (27%) | catalogued as COSV52660835; called by muse, mutect2, varscan2
- NLRP9 | c.2696G>A p.R899H | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs199518376, COSV60459247; called by muse, mutect2, varscan2
- NMBR | c.727G>A p.A243T | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0.082); catalogued as rs147317413; called by muse, mutect2, varscan2
- NMT2 | c.1124A>C p.H375P | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1435668095, COSV65382937; called by muse, mutect2, varscan2
- NOL11 | c.1335A>C p.K445N | Missense Mutation (SNP) | VAF 44/165 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.444); catalogued as COSV53524956; called by muse, mutect2, varscan2
- NOLC1 | c.840del p.K280Nfs*3 | Frame Shift Del (DEL) | VAF 20/74 reads (27%) | catalogued as rs759637346; called by mutect2, varscan2
- NOP14 | c.2171C>T p.A724V | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as rs376459415; called by muse, mutect2
- NOS1 | c.2027del p.G676Afs*64 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | catalogued as rs746543323; called by pindel, varscan2
- NOXRED1 | c.25T>C p.S9P | Missense Mutation (SNP) | VAF 46/215 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV53628846; called by muse, mutect2, varscan2
- NPAS4 | c.1448G>T p.S483I | Missense Mutation (SNP) | VAF 108/428 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.363); catalogued as COSV60652069; called by muse, mutect2, varscan2
- NPAT | c.1727A>G p.H576R | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.122); catalogued as COSV53720749; called by muse, mutect2, varscan2
- NPFFR2 | c.1372del p.R458Efs*10 | Frame Shift Del (DEL) | VAF 28/113 reads (25%) | catalogued as rs1405220543; called by mutect2, pindel, varscan2
- NPHP1 | c.460G>A p.G154S | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs769509705, COSV57208510; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NPRL3 | c.340C>A p.P114T | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV67854220; called by muse, mutect2, varscan2
- NPTN | c.815G>A p.R272H | Missense Mutation (SNP) | VAF 34/153 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0.009); catalogued as rs369855294; called by muse, mutect2, varscan2
- NR4A1 | c.52C>T p.R18C | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs377043577; called by muse, mutect2, varscan2
- NRIP1 | c.679A>G p.T227A | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT tolerated (0.56); PolyPhen benign (0.01); catalogued as COSV59657162; called by muse, mutect2, varscan2
- NRROS | c.472T>C p.S158P | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV60747234; called by muse, mutect2, varscan2
- NRXN2 | c.2874C>A p.N958K | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV55460819; called by muse, mutect2
- NRXN2 | c.955C>T p.R319C | Missense Mutation (SNP) | VAF 40/164 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.189); catalogued as rs1442718795, COSV55447870; called by muse, mutect2, varscan2
- NRXN3 | c.215T>G p.V72G | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.151); catalogued as COSV73586521; called by muse, mutect2, varscan2
- NRXN3 | c.2951A>C p.K984T (on ENST00000335750 / NM_001330195.2; = p.K611T on NM_004796.6) | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.986); catalogued as COSV59790698; called by muse, mutect2, varscan2
- NSD2 | c.3995C>T p.S1332L | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs561070783, COSV56389229; called by muse, mutect2, varscan2
- NTM | c.1019T>C p.L340P | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as COSV66211795; called by muse, mutect2, varscan2
- NTN4 | c.109C>T p.R37W | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.906); catalogued as rs748149271, COSV59222760; called by muse, mutect2, varscan2
- NUP160 | c.2537C>A p.P846H | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.339); catalogued as COSV65855493; called by muse, mutect2, varscan2
- NUP210 | c.769A>G p.T257A | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT tolerated (0.64); PolyPhen benign (0.009); catalogued as rs747754565, COSV54411741; called by muse, mutect2, varscan2
- NUP210L | c.3332A>G p.Q1111R | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV55154784; called by muse, mutect2, varscan2
- NUP42 | c.475A>G p.R159G | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51730857; called by muse, mutect2, varscan2
- NUP85 | c.311A>T p.N104I | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV55466046; called by muse, mutect2, varscan2
- NUP98 | c.5267G>A p.R1756H (on ENST00000359171 / NM_001365126.1; = p.R1739H on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs763063541, COSV51708728; called by muse, mutect2, varscan2
- NUSAP1 | c.616A>G p.K206E | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs773154411, COSV52972664; called by muse, mutect2, varscan2
- NVL | c.956C>T p.A319V | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55875162; called by muse, mutect2
- OAS3 | c.2458G>A p.V820M | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1469114070, COSV57446407; called by muse, mutect2, varscan2
- OGFOD1 | c.713A>G p.H238R | Missense Mutation (SNP) | VAF 48/179 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV60201238; called by muse, mutect2, varscan2
- OR10AG1 | c.858A>T p.K286N | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV56634279; called by muse, mutect2, varscan2
- OR10G4 | c.286T>G p.C96G | Missense Mutation (SNP) | VAF 32/184 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100304811; called by muse, varscan2
- OR10G7 | c.355T>C p.Y119H | Missense Mutation (SNP) | VAF 38/213 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV57865779; called by muse, mutect2
- OR10P1 | c.721A>G p.T241A | Missense Mutation (SNP) | VAF 21/198 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59008243; called by muse, mutect2, varscan2
- OR1A1 | c.110T>C p.I37T | Missense Mutation (SNP) | VAF 48/179 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs571378546, COSV58404452; called by muse, mutect2, varscan2
- OR4C15 | c.509C>T p.A170V (on ENST00000314644; = p.A116V on NM_001001920.2) | Missense Mutation (SNP) | VAF 42/146 reads (29%) | SIFT tolerated, low confidence (0.98); PolyPhen benign (0.046); catalogued as rs201255343; called by muse, mutect2, varscan2
- OR4D5 | c.629G>A p.C210Y | Missense Mutation (SNP) | VAF 78/311 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.425); catalogued as COSV58308877; called by muse, mutect2, varscan2
- OR4K13 | c.763G>T p.V255F | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV59860498; called by muse, mutect2, varscan2
- OR4L1 | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 34/164 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as rs1351242552, COSV59850924; called by muse, mutect2, varscan2
- OR4M1 | c.455del p.G152Afs*6 | Frame Shift Del (DEL) | VAF 60/356 reads (17%) | catalogued as rs760267821, COSV60064156; called by mutect2, pindel, varscan2
- OR51B6 | c.823A>T p.S275C | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV66513721; called by muse, mutect2, varscan2
- OR51E2 | c.467del p.F156Sfs*6 | Frame Shift Del (DEL) | VAF 29/106 reads (27%) | catalogued as rs755413956; called by mutect2, varscan2
- OR51L1 | c.377T>C p.V126A | Missense Mutation (SNP) | VAF 66/221 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.089); catalogued as COSV58625433; called by muse, mutect2, varscan2
- OR52E8 | c.55C>A p.L19I | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.027); catalogued as COSV66210717; called by muse, mutect2, varscan2
- OR52J3 | c.933del p.K311Nfs*? | Frame Shift Del (DEL) | VAF 8/43 reads (19%) | catalogued as rs1254479213; called by mutect2, pindel
- OR52N2 | c.230C>T p.T77I | Missense Mutation (SNP) | VAF 44/174 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.495); catalogued as COSV57677553; called by muse, varscan2
- OR56B1 | c.878dup p.S294Ffs*15 | Frame Shift Ins (INS) | VAF 64/341 reads (19%) | catalogued as rs1564953116; called by mutect2, pindel, varscan2
- OR5M8 | c.786dup p.S263Lfs*6 | Frame Shift Ins (INS) | VAF 6/52 reads (12%) | catalogued as rs760237003; called by mutect2, pindel
- OR5W2 | c.700A>G p.R234G | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.25); catalogued as COSV60617204; called by muse, mutect2, varscan2
- OR6K6 | c.544C>A p.L182I (on ENST00000368144; = p.L158I on NM_001005184.1) | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.122); catalogued as COSV63744686; called by muse, mutect2, varscan2
- OR8G1 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV100422386; called by muse, mutect2, varscan2
- ORC1 | c.2111C>T p.A704V | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV65364859; called by muse, mutect2, varscan2
- ORC3 | c.610del p.R204Gfs*16 | Frame Shift Del (DEL) | VAF 16/81 reads (20%) | catalogued as rs1336736903; called by mutect2, pindel, varscan2
- OSBPL9 | c.1100C>A p.S367Y | Missense Mutation (SNP) | VAF 43/155 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV100542910, COSV61873662; called by muse, mutect2, varscan2
- OTUD3 | c.1151A>G p.N384S | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV64296310; called by muse, mutect2, varscan2
- OTUD7A | c.566G>A p.W189* | Nonsense Mutation (SNP) | VAF 21/79 reads (27%) | catalogued as COSV61042060; called by muse, mutect2, varscan2
- P2RX4 | c.206A>G p.K69R | Missense Mutation (SNP) | VAF 53/226 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58742703; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.1059A>C p.E353D (on ENST00000374531 / NM_001037293.2; = p.E385D on NM_053016.6) | Missense Mutation (SNP) | VAF 11/129 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.067); catalogued as COSV57129324; called by muse, mutect2
- PANK2 | c.1174T>G p.S392A (on ENST00000316562 / NM_153638.3; = p.S101A on NM_024960.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV57255952; called by muse, mutect2, varscan2
- PAPLN | c.868G>A p.G290S (on ENST00000554301; = p.G263S on NM_173462.4) | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs141937638, COSV99390610; called by muse, mutect2, varscan2
- PAPPA2 | c.1838G>A p.R613H | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.985); catalogued as rs571958730, COSV100866525, COSV62779593; called by muse, mutect2, varscan2
- PARP12 | c.901T>C p.W301R | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54936394; called by muse, mutect2, varscan2
- PATZ1 | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.025); catalogued as COSV53228993, COSV53230820; called by muse, mutect2, varscan2
- PCDHA1 | c.1522G>A p.V508M | Missense Mutation (SNP) | VAF 34/175 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as rs1167626504, COSV65372718; called by muse, mutect2, varscan2
- PCDHA2 | c.2159C>T p.A720V | Missense Mutation (SNP) | VAF 62/198 reads (31%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.021); catalogued as rs1173603026, COSV65370120; called by muse, mutect2, varscan2
- PCDHA7 | c.1120G>A p.V374M | Missense Mutation (SNP) | VAF 51/239 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.978); catalogued as COSV65343835; called by muse, mutect2, varscan2
- PCDHB13 | c.979A>G p.T327A | Missense Mutation (SNP) | VAF 48/170 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.081); catalogued as rs781852196, COSV99507154; called by muse, mutect2, varscan2
- PCDHB3 | c.1988T>C p.V663A | Missense Mutation (SNP) | VAF 46/235 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.792); catalogued as COSV50611067; called by muse, mutect2, varscan2
- PCDHB5 | c.1420G>A p.A474T | Missense Mutation (SNP) | VAF 99/365 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50651022; called by muse, varscan2
- PCDHB6 | c.1873G>A p.A625T | Missense Mutation (SNP) | VAF 44/161 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.022); catalogued as COSV50701759, COSV50709609; called by muse, mutect2, varscan2
- PCDHGA11 | c.1742G>A p.R581H | Missense Mutation (SNP) | VAF 14/314 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.344); catalogued as COSV54006472; called by muse, mutect2
- PCDHGA2 | c.1676C>T p.A559V | Missense Mutation (SNP) | VAF 85/356 reads (24%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.033); catalogued as rs746420859, COSV54006428, COSV54036882; called by muse, mutect2, varscan2
- PCDHGA6 | c.1670A>G p.D557G | Missense Mutation (SNP) | VAF 72/323 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV54006443; called by muse, mutect2, varscan2
- PCDHGB4 | c.1520C>T p.A507V | Missense Mutation (SNP) | VAF 31/136 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.223); catalogued as COSV53960181; called by muse, mutect2, varscan2
- PCDHGB5 | c.1624G>A p.V542M | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.719); catalogued as rs564705346, COSV53894578; called by muse, mutect2, varscan2
- PCDHGC4 | c.1411G>T p.G471W | Missense Mutation (SNP) | VAF 46/181 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52763051; called by muse, mutect2, varscan2
- PCLO | c.1441C>A p.P481T | Missense Mutation (SNP) | VAF 44/163 reads (27%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV61657411, COSV61657490; called by muse, mutect2, varscan2
- PCNT | c.1406G>A p.R469H | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs776782829, COSV64031804; called by muse, mutect2, varscan2
- PCNX1 | c.2114A>G p.N705S | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV53099691; called by muse, mutect2, varscan2
- PCNX1 | c.5957A>G p.D1986G | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53099703; called by muse, mutect2
- PCSK5 | c.3470G>A p.R1157H | Missense Mutation (SNP) | VAF 45/150 reads (30%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs777222949, COSV101377352; called by muse, mutect2, varscan2
- PDE4DIP | c.5034G>T p.L1678F | Missense Mutation (SNP) | VAF 52/247 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.249); catalogued as COSV57720078; called by muse, mutect2, varscan2
- PDLIM5 | c.1283G>T p.R428I | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58751415; called by muse, varscan2
- PEAK1 | c.890G>A p.R297Q | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs759331417, COSV56934716; called by muse, mutect2, varscan2
- PEPD | c.463G>A p.G155S | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as rs759069264, COSV54894564; called by muse, mutect2, varscan2
- PGBD5 | c.454C>T p.R152C (on ENST00000525115; = p.R221C on NM_001258311.2) | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1390100566, COSV100358404, COSV58413111; called by muse, mutect2, varscan2
- PGGHG | c.2029G>A p.V677I | Missense Mutation (SNP) | VAF 60/204 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.086); catalogued as rs757743854, COSV66888494; called by muse, varscan2
- PGK1 | c.26T>G p.L9R | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV64832542; called by muse, mutect2, varscan2
- PGLYRP2 | c.1520C>T p.A507V | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52996809; called by muse, mutect2
- PGLYRP4 | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 34/185 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as rs907883393, COSV62836092; called by muse, mutect2, varscan2
- PHACTR1 | c.759dup p.P254Afs*78 | Frame Shift Ins (INS) | VAF 34/112 reads (30%) | catalogued as rs749326031; called by mutect2, varscan2
- PHACTR2 | c.1850C>A p.T617K | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.066); catalogued as COSV59857422; called by muse, mutect2, varscan2
- PHACTR2 | c.1895A>G p.H632R | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV59857433; called by muse, mutect2, varscan2
- PHACTR4 | c.160del p.S54Vfs*12 (on ENST00000373839 / NM_001350159.2; = p.S64Vfs*12 on NM_023923.4) | Frame Shift Del (DEL) | VAF 12/54 reads (22%) | catalogued as rs761437290, COSV65783432; called by mutect2, varscan2
- PHGDH | c.884G>A p.C295Y | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65572084; called by muse, mutect2, varscan2
- PHLPP2 | c.145A>G p.T49A | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as COSV62422747, COSV62426684; called by muse, mutect2, varscan2
- PHTF1 | c.1637del p.F546Sfs*2 | Frame Shift Del (DEL) | VAF 11/40 reads (28%) | catalogued as rs750248180; called by mutect2, varscan2
- PHYHIPL | c.449G>A p.W150* | Nonsense Mutation (SNP) | VAF 21/80 reads (26%) | catalogued as rs759369880, COSV65849722; called by muse, mutect2, varscan2
- PI16 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1016531209, COSV65448542; called by muse, mutect2, varscan2
- PIAS4 | c.274C>T p.R92W | Missense Mutation (SNP) | VAF 40/159 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.332); catalogued as rs754930081, COSV53680610; called by muse, mutect2, varscan2
- PIEZO2 | c.7597dup p.S2533Ffs*20 | Frame Shift Ins (INS) | VAF 14/66 reads (21%) | catalogued as rs1451012640; called by mutect2, pindel, varscan2
- PIGK | c.1071+2T>G p.X357_splice | Splice Site (SNP) | VAF 12/44 reads (27%) | catalogued as COSV63652798; called by muse, varscan2
- PIGT | c.1043dup p.V349Sfs*99 | Frame Shift Ins (INS) | VAF 10/54 reads (19%) | catalogued as rs749895437; called by mutect2, varscan2
- PIK3AP1 | c.620C>T p.A207V | Missense Mutation (SNP) | VAF 48/207 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.038); catalogued as rs201029174, COSV59535870; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PIK3C2A | c.1382A>G p.D461G | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56405750; called by muse, mutect2, varscan2
- PITPNM2 | c.2963A>T p.K988M | Missense Mutation (SNP) | VAF 60/252 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV54906262; called by muse, mutect2, varscan2
- PLCE1 | c.3001G>A p.G1001R | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs376113551, COSV53355442; called by muse, mutect2, varscan2
- PLCE1 | c.4763A>G p.E1588G | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.947); catalogued as rs1282534937, COSV53365729; called by muse, mutect2, varscan2
- PLCG1 | c.1675C>T p.R559C | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs765759937, COSV54822455; called by muse, mutect2, varscan2
- PLCG2 | c.2310T>C p.P770= | Splice Region (SNP) | VAF 12/29 reads (41%) | catalogued as COSV63874212; called by muse, mutect2, varscan2
- PLCH2 | c.1688G>T p.G563V | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.313); catalogued as rs1019597888, COSV53946210; called by muse, mutect2, varscan2
- PLEKHA2 | c.633G>T p.V211= | Splice Region (SNP) | VAF 7/36 reads (19%) | catalogued as COSV66243311; called by muse, mutect2, varscan2
- PLEKHA5 | c.929dup p.N310Kfs*8 | Frame Shift Ins (INS) | VAF 10/40 reads (25%) | catalogued as rs1565550899; called by mutect2, varscan2
- PLEKHG3 | c.673C>T p.R225W (on ENST00000394691; = p.R281W on NM_001308147.2) | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762306034, COSV55982690; called by muse, mutect2, varscan2
- PLEKHO2 | c.980A>T p.E327V | Missense Mutation (SNP) | VAF 7/117 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as COSV60262735; called by muse, mutect2
- PLPP6 | c.763C>T p.R255W | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.376); catalogued as COSV56306675; called by muse, mutect2, varscan2
- PLXNC1 | c.2977C>T p.R993C | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51581089; called by muse, mutect2, varscan2
- PLXND1 | c.4247T>C p.L1416P | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60717871; called by muse, mutect2, varscan2
- PLXND1 | c.2022dup p.N675Qfs*8 | Frame Shift Ins (INS) | VAF 36/125 reads (29%) | catalogued as rs747702371; called by mutect2, varscan2
- PNPLA6 | c.3673C>T p.R1225C (on ENST00000414982 / NM_001166111.2; = p.R1177C on NM_006702.5) | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55383214; called by muse, mutect2, varscan2
- PODN | c.908del p.P303Rfs*7 (on ENST00000395871; = p.P255Rfs*7 on NM_153703.5 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 60/284 reads (21%) | catalogued as rs1464111568, COSV57017199; called by mutect2, pindel, varscan2
- PODN | c.1109G>A p.R370Q (on ENST00000395871; = p.R322Q on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as rs748844816, COSV57016258; called by muse, mutect2, varscan2
- PODNL1 | c.904G>A p.G302R | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs758408194, COSV54309533; called by muse, mutect2, varscan2
- POLD1 | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs201010746, COSV70956748; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLR1B | c.1329A>G p.T443= | Splice Region (SNP) | VAF 8/27 reads (30%) | catalogued as COSV54502032; called by muse, mutect2, varscan2
- POLR2A | c.4808G>A p.R1603H | Missense Mutation (SNP) | VAF 75/313 reads (24%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.737); catalogued as rs1036541727; called by muse, mutect2, varscan2
- POM121C | c.1873C>A p.L625I (on ENST00000607367; = p.L383I on NM_001099415.3) | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV99992642; called by mutect2, varscan2
- POM121L12 | c.377G>T p.R126L | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.605); catalogued as COSV68692958, COSV68693988; called by muse, varscan2
- POM121L12 | c.506T>C p.L169P | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.557); catalogued as COSV68693992; called by muse, varscan2
1,042 further variants in this file (633 protein-altering or splice-affecting, 369 silent, 40 other) are not listed here.
